Somatic mutation profile of tumor specimen TCGA-B5-A11Y-01A (aliquot TCGA-B5-A11Y-01A-21D-A10M-09) from TCGA case TCGA-B5-A11Y, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, secretory variant; Tissue or organ of origin: Endometrium; FIGO stage: Stage IB; Tumor grade: G1; Age at diagnosis: 59.8 years (21,860 days).
Specimen TCGA-B5-A11Y-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f684411e-64c6-4fde-87ab-878d75bb44d0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B5-A11Y-10A (Blood Derived Normal), aliquot TCGA-B5-A11Y-10A-01D-A10M-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/928a7ec8-145f-4e89-ab44-b18f7e5f14d9

The open-access MAF lists 1,204 somatic variants for this specimen: 838 protein-altering or splice-affecting, 340 silent, 26 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 751, Silent 340, Nonsense Mutation 36, Frame Shift Del 19, Splice Region 16, Intron 11, RNA 8, Splice Site 7, In Frame Del 5, 3'UTR 3, 5'UTR 2, Frame Shift Ins 2.

Variants (750 of 1,204; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACADS | c.973C>T p.R325W | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs121908006, CM010007, COSV99656717, COSV99656767; ClinVar: pathogenic / uncertain significance; called by muse, mutect2
- ADNP | c.673C>T p.R225* | Nonsense Mutation (SNP) | VAF 25/117 reads (21%) | catalogued as rs1057518991, COSV62426779; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- BCL2L11 | c.466G>A p.G156R (on ENST00000393256 / NM_138621.5; = p.G96R on NM_006538.5) | Missense Mutation (SNP) | VAF 20/92 reads (22%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775080943, COSV58028355, COSV58033623; called by muse, mutect2, varscan2
- CASR | c.1378-6285G>A | Intron (SNP) | VAF 10/44 reads (23%) | catalogued as rs104893716, CM060892, COSV99949243; ClinVar: pathogenic / uncertain significance; called by muse, mutect2, varscan2
- CREBBP | c.5344G>A p.A1782T | Missense Mutation (SNP) | VAF 47/192 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs1567263529, COSV52140133; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- CTCF | c.1342C>T p.R448* | Nonsense Mutation (SNP) | VAF 15/109 reads (14%) | hotspot (GDC flag); catalogued as rs769948988, COSV50461776; called by muse, mutect2, varscan2
- FGFR2 | c.1124A>G p.Y375C | Missense Mutation (SNP) | VAF 37/97 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs121913478, CM960653, COSV60640350; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- GJA3 | c.260C>T p.T87M | Missense Mutation (SNP) | VAF 135/448 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs864309687, CM071794, COSV53834152; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KCNH2 | c.1655T>C p.L552S | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs199472918, CM002300, COSV51226480; ClinVar: not provided / pathogenic; called by muse, varscan2
- MYO7A | c.1969C>T p.R657W | Missense Mutation (SNP) | VAF 35/124 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs878853236, CM071032, COSV68686962; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- NEDD4L | c.2677G>A p.E893K (on ENST00000400345 / NM_001144967.3; = p.E873K on NM_015277.6) | Missense Mutation (SNP) | VAF 54/189 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as rs879255597, COSV56842960; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.278G>A p.R93Q | Missense Mutation (SNP) | VAF 14/55 reads (25%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.867); catalogued as rs1064793663, COSV55877982, COSV55886419, COSV56022812; ClinVar: pathogenic; called by muse, varscan2
- PIK3CA | c.1030G>A p.V344M | Missense Mutation (SNP) | VAF 10/36 reads (28%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs1057519942, COSV55881590; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.3141T>A p.H1047Q | Missense Mutation (SNP) | VAF 11/32 reads (34%) | hotspot (GDC flag); SIFT tolerated (0.24); PolyPhen benign (0.009); catalogued as COSV55875891, COSV55920782; called by muse, mutect2, varscan2
- PTEN | c.388C>T p.R130* | Nonsense Mutation (SNP) | VAF 30/59 reads (51%) | hotspot (GDC flag); catalogued as rs121909224, CM094223, CM971273, COSV64288384, COSV64288463, COSV64297940, COSV64311187; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SPOP | c.393G>T p.W131C | Missense Mutation (SNP) | VAF 11/71 reads (15%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs1057519970, COSV61653780, COSV61655224; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- WDR45 | c.827+1G>A p.X276_splice (on ENST00000376372 / NM_001029896.2; = p.X277_splice on NM_007075.3) | Splice Site (SNP) | VAF 32/149 reads (21%) | catalogued as rs1557083958, CS1211569, COSV100540289, COSV59876430, COSV59876939; ClinVar: pathogenic / not provided; called by muse, mutect2, varscan2
- AAMDC | c.268A>G p.I90V | Missense Mutation (SNP) | VAF 12/109 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV59021070; called by muse, mutect2, varscan2
- ABAT | c.1054G>A p.V352M | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.125); catalogued as rs775462540, COSV51621435, COSV51628035; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABCB6 | c.2447G>A p.G816E | Missense Mutation (SNP) | VAF 102/384 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54700183; called by muse, mutect2, varscan2
- ABCC11 | c.3862A>T p.I1288F | Missense Mutation (SNP) | VAF 31/99 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.561); catalogued as COSV62325765; called by muse, mutect2, varscan2
- ABCC2 | c.1283C>A p.A428D | Missense Mutation (SNP) | VAF 25/94 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV64988503; called by muse, mutect2, varscan2
- ABRA | c.110C>T p.A37V | Missense Mutation (SNP) | VAF 29/119 reads (24%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.721); catalogued as rs762870434, COSV61733543; called by muse, mutect2, varscan2
- ACAN | c.517C>T p.R173W | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs374211268; called by muse, mutect2, varscan2
- ACER1 | c.640A>G p.S214G | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.828); catalogued as COSV56836914; called by muse, mutect2, varscan2
- ACSL6 | c.1187G>A p.R396H (on ENST00000379240; = p.R421H on NM_015256.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.348); catalogued as rs766232398, COSV57304694; called by muse, mutect2, varscan2
- ACTN4 | c.1586T>C p.L529P | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV53150308; called by muse, mutect2, varscan2
- ADAM8 | c.1352G>A p.G451D | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV101291697; called by muse, mutect2, varscan2
- ADAMTS9 | c.2242G>A p.D748N | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.172); catalogued as rs1175160416, COSV55776673; called by muse, mutect2, varscan2
- ADARB2 | c.1690G>A p.V564I | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.251); catalogued as COSV67182835; called by muse, mutect2
- ADCY7 | c.433C>T p.R145W | Missense Mutation (SNP) | VAF 44/177 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs141967597; called by muse, mutect2, varscan2
- ADGRB2 | c.1886G>A p.R629H | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.947); catalogued as rs1198638899, COSV57074009; called by muse, mutect2, varscan2
- ADGRE5 | c.1469G>A p.R490Q (on ENST00000242786 / NM_078481.4; = p.R397Q on NM_001784.5) | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.129); catalogued as rs549360964, COSV54393305; called by muse, mutect2, varscan2
- ADRA1A | c.730G>A p.G244R | Missense Mutation (SNP) | VAF 29/125 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.094); catalogued as rs1389708992, COSV52373427; called by muse, mutect2, varscan2
- AFAP1L1 | c.1113C>T p.H371= | Splice Region (SNP) | VAF 21/92 reads (23%) | catalogued as rs144806146; called by muse, mutect2, varscan2
- AGAP2 | c.2021G>A p.R674Q (on ENST00000547588 / NM_001122772.2; = p.R338Q on NM_014770.4) | Missense Mutation (SNP) | VAF 84/311 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs374639452; called by muse, mutect2, varscan2
- AHCYL1 | c.1180G>A p.V394I | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.165); catalogued as rs747665671, COSV63209372; called by muse, mutect2, varscan2
- AHNAK2 | c.10651G>A p.G3551S | Missense Mutation (SNP) | VAF 79/313 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.053); catalogued as rs199591478; called by muse, mutect2, varscan2
- AHRR | c.1358C>A p.P453Q | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT tolerated (0.59); PolyPhen benign (0.221); catalogued as COSV57085012, COSV57093294; called by muse, mutect2, varscan2
- AHSG | c.836C>T p.P279L | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as rs1426415837, COSV56607382; called by muse, mutect2, varscan2
- AK7 | c.1586A>G p.E529G | Missense Mutation (SNP) | VAF 21/106 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.597); catalogued as COSV50881873; called by muse, mutect2, varscan2
- ALDOA | c.763C>T p.R255C (on ENST00000642816 / NM_001243177.4; = p.R201C on NM_184041.5) | Missense Mutation (SNP) | VAF 41/242 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.017); catalogued as rs372394541, COSV57633972; called by muse, mutect2, varscan2
- ALG12 | c.768G>A p.G256= | Splice Region (SNP) | VAF 57/218 reads (26%) | catalogued as COSV58208402; called by muse, mutect2, varscan2
- ALKAL2 | c.332G>A p.C111Y | Missense Mutation (SNP) | VAF 99/530 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60416972; called by muse, mutect2, varscan2
- ALOX15B | c.829A>G p.S277G | Missense Mutation (SNP) | VAF 57/214 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.933); catalogued as COSV66480158; called by muse, mutect2, varscan2
- AMN1 | c.649A>G p.T217A | Missense Mutation (SNP) | VAF 10/121 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.024); catalogued as COSV99861624; called by muse, mutect2
- AMOTL2 | c.1394C>T p.A465V | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as rs1487351364, COSV51440255; called by mutect2, varscan2
- ANGPTL8 | c.388G>A p.V130M | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT tolerated (0.22); PolyPhen benign (0.133); catalogued as rs79566395, COSV99371064; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.3292G>A p.A1098T | Missense Mutation (SNP) | VAF 23/106 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV51857775; called by muse, mutect2, varscan2
- ANKRD50 | c.2792T>A p.L931* | Nonsense Mutation (SNP) | VAF 13/41 reads (32%) | catalogued as COSV72386274; called by muse, mutect2, varscan2
- ANO3 | c.1883G>C p.R628P | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56807795, COSV99882662; called by muse, mutect2, varscan2
- AP1M2 | c.802C>T p.R268C | Missense Mutation (SNP) | VAF 40/150 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1383931855, COSV51569372; called by muse, mutect2, varscan2
- AP4B1 | c.1460G>A p.R487Q | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs375080258; called by muse, mutect2, varscan2
- AP4M1 | c.158G>A p.G53D | Missense Mutation (SNP) | VAF 123/597 reads (21%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as COSV100385059; called by muse, mutect2, varscan2
- AP5M1 | c.1387G>A p.A463T | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55106856; called by muse, mutect2, varscan2
- APOL1 | c.112G>A p.V38I | Missense Mutation (SNP) | VAF 34/146 reads (23%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs200488315, COSV59869831; called by muse, mutect2, varscan2
- APOL3 | c.512G>A p.R171H (on ENST00000349314 / NM_145640.2; = p.R100H on NM_014349.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 37/155 reads (24%) | SIFT tolerated (0.55); PolyPhen benign (0.013); catalogued as rs577244594, COSV62579985; called by muse, mutect2, varscan2
- ARAP2 | c.1084C>T p.L362F | Missense Mutation (SNP) | VAF 20/99 reads (20%) | SIFT tolerated (0.49); PolyPhen benign (0.109); catalogued as COSV58291834; called by muse, mutect2, varscan2
- ARFGAP1 | c.884C>T p.S295L | Missense Mutation (SNP) | VAF 61/307 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.158); catalogued as rs200768802, COSV62262582; called by muse, mutect2, varscan2
- ARHGAP24 | c.2102T>C p.M701T (on ENST00000395184 / NM_001025616.3; = p.M608T on NM_031305.3) | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.104); catalogued as rs753293329, COSV51993385; called by muse, mutect2, varscan2
- ARHGAP27 | c.1064G>A p.R355Q (on ENST00000428638 / NM_001282290.1; = p.R14Q on NM_199282.3) | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.886); catalogued as rs1445974764, COSV100976453, COSV65358688; called by muse, mutect2, varscan2
- ARHGAP35 | c.1585C>T p.R529* | Nonsense Mutation (SNP) | VAF 15/77 reads (19%) | catalogued as COSV68328962; called by muse, mutect2, varscan2
- ARHGAP35 | c.2587C>T p.R863C | Missense Mutation (SNP) | VAF 49/189 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68330957; called by muse, mutect2, varscan2
- ARHGAP5 | c.4228T>A p.S1410T (on ENST00000345122 / NM_001030055.2; = p.S1409T on NM_001173.3) | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV53735595; called by muse, mutect2, varscan2
- ARHGEF1 | c.541C>T p.R181W | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as rs782100845, COSV61529571; called by muse, mutect2, varscan2
- ARHGEF40 | c.2695C>T p.R899W | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.034); catalogued as rs748174369, COSV53883922; called by muse, mutect2, varscan2
- ARHGEF5 | c.83T>C p.M28T | Missense Mutation (SNP) | VAF 20/178 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as rs752412737, COSV50218702; called by mutect2, varscan2
- ARID4B | c.988C>T p.R330* | Nonsense Mutation (SNP) | VAF 14/66 reads (21%) | catalogued as COSV51607689; called by muse, mutect2
- ARMCX1 | c.730C>T p.R244C | Missense Mutation (SNP) | VAF 27/123 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs781882847, COSV65705529; called by muse, mutect2, varscan2
- ARMH4 | c.749T>C p.L250P | Missense Mutation (SNP) | VAF 26/117 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.027); catalogued as COSV50773235; called by muse, mutect2, varscan2
- ARRB2 | c.918C>T p.I306= | Splice Region (SNP) | VAF 80/344 reads (23%) | catalogued as rs749565343, COSV52619006; called by muse, mutect2, varscan2
- ARSJ | c.50C>T p.A17V | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as rs761085854, COSV59539734; called by muse, mutect2, varscan2
- ASB5 | c.935T>C p.L312P | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.995); catalogued as COSV56674202; called by muse, mutect2, varscan2
- ASB7 | c.190C>T p.R64W | Missense Mutation (SNP) | VAF 40/142 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV58404574; called by muse, mutect2, varscan2
- ATAD5 | c.4240C>T p.R1414* | Nonsense Mutation (SNP) | VAF 21/73 reads (29%) | catalogued as COSV58978707; called by muse, mutect2, varscan2
- ATG9A | c.1010G>A p.R337H | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as rs766730899, COSV63445891; called by muse, mutect2, varscan2
- ATP1A4 | c.2143G>T p.G715* | Nonsense Mutation (SNP) | VAF 29/133 reads (22%) | catalogued as COSV63628448; called by muse, mutect2, varscan2
- ATP1B1 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 19/71 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV63180108; called by muse, mutect2, varscan2
- ATP2A1 | c.2230G>A p.V744I | Missense Mutation (SNP) | VAF 16/366 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.465); catalogued as rs866421756, COSV100707138; called by muse, mutect2
- AURKB | c.80G>A p.R27Q | Missense Mutation (SNP) | VAF 78/320 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.148); catalogued as rs370931710; called by muse, mutect2, varscan2
- B4GALT3 | c.364C>T p.R122C | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as rs202068319, COSV60527589; called by muse, mutect2, varscan2
- BACH1 | c.1444_1446del p.D482del | In Frame Del (DEL) | VAF 8/40 reads (20%) | catalogued as rs1420269275; called by pindel, varscan2
- BAIAP2L1 | c.1001C>T p.T334M | Missense Mutation (SNP) | VAF 80/324 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs745321866, COSV50057211; called by muse, mutect2
- BAP1 | c.1484C>T p.T495M | Missense Mutation (SNP) | VAF 27/120 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56232489; called by muse, mutect2, varscan2
- BATF | c.175G>A p.E59K | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV54375846; called by muse, mutect2, varscan2
- BAX | c.484C>A p.L162I | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.503); catalogued as COSV53171750; called by muse, mutect2, varscan2
- BCHE | c.23T>C p.I8T | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as COSV52262208; called by muse, mutect2, varscan2
- BCL6B | c.1090C>T p.R364C | Missense Mutation (SNP) | VAF 46/140 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV53430147; called by muse, mutect2, varscan2
- BFSP2 | c.460C>T p.R154W | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as rs752477155, COSV56586351; called by muse, mutect2, varscan2
- BRCA2 | c.3476G>A p.C1159Y | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV66462061; called by muse, mutect2, varscan2
- BRK1 | c.176G>A p.R59Q | Missense Mutation (SNP) | VAF 43/165 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.027); catalogued as rs746376520, COSV56542175; called by muse, mutect2, varscan2
- BRPF1 | c.1472G>A p.R491Q | Missense Mutation (SNP) | VAF 25/171 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.049); catalogued as rs755029827, COSV57407901; called by muse, mutect2, varscan2
- BRWD3 | c.1408G>A p.V470I | Missense Mutation (SNP) | VAF 15/91 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs1411652690, COSV64753448; called by muse, mutect2, varscan2
- BTBD1 | c.941G>A p.R314Q | Missense Mutation (SNP) | VAF 28/95 reads (29%) | SIFT tolerated (0.41); PolyPhen benign (0.007); catalogued as COSV55603550; called by muse, mutect2, varscan2
- BTBD11 | c.1223C>T p.S408L | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (0.46); PolyPhen benign (0.048); catalogued as rs376834648; called by muse, mutect2, varscan2
- BTBD7 | c.1996C>T p.H666Y | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.259); catalogued as COSV100598022; called by muse, mutect2
- BTBD7 | c.1714C>T p.R572C | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs368923940; called by muse, mutect2, varscan2
- BTD | c.1093A>G p.K365E | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (0.54); PolyPhen benign (0.001); catalogued as COSV57730535; called by muse, mutect2, varscan2
- BTN1A1 | c.1120G>A p.V374M | Missense Mutation (SNP) | VAF 30/139 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs778400918, COSV55067292; called by muse, mutect2, varscan2
- BTNL3 | c.907G>A p.V303I | Missense Mutation (SNP) | VAF 27/136 reads (20%) | SIFT tolerated (0.72); PolyPhen benign (0.039); catalogued as rs1403791692, COSV61565329; called by muse, mutect2, varscan2
- C12orf4 | c.1368A>G p.I456M | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV54209597; called by muse, mutect2, varscan2
- C14orf119 | c.26T>C p.M9T | Missense Mutation (SNP) | VAF 24/283 reads (8%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as COSV99399960; called by muse, mutect2
- C18orf32 | c.100C>T p.R34C | Missense Mutation (SNP) | VAF 84/337 reads (25%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.953); catalogued as rs201224790, COSV59088464; called by muse, mutect2, varscan2
- C1QTNF9B | c.139G>A p.G47R | Missense Mutation (SNP) | VAF 118/658 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs370293437; called by muse, varscan2
- C1orf105 | c.101C>A p.P34H | Missense Mutation (SNP) | VAF 24/153 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV51130894, COSV51131396; called by muse, mutect2, varscan2
- C1orf127 | c.958G>A p.G320R | Missense Mutation (SNP) | VAF 36/159 reads (23%) | SIFT tolerated (0.56); PolyPhen benign (0.046); catalogued as rs762535489, COSV65438865; called by muse, mutect2, varscan2
- C4orf19 | c.785A>G p.H262R | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT tolerated (0.64); PolyPhen benign (0.005); catalogued as rs768230851, COSV52650264; called by muse, mutect2, varscan2
- C8orf74 | c.577C>T p.R193W | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.409); catalogued as rs766024547, COSV58755713; called by muse, mutect2
- CA8 | c.614C>T p.T205I | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.026); catalogued as COSV58774480; called by muse, mutect2, varscan2
- CABP4 | c.472A>G p.M158V | Missense Mutation (SNP) | VAF 32/123 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1216281734, COSV56888058; called by muse, mutect2, varscan2
- CACNA1C | c.340C>T p.R114W | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs758229132, COSV59768190; called by muse, mutect2, varscan2
- CACNA1D | c.1750G>A p.V584I (on ENST00000350061 / NM_001128840.3; = p.V604I on NM_000720.4) | Missense Mutation (SNP) | VAF 99/379 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.87); catalogued as rs773365038, COSV55436324, COSV55437532; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CACNA1I | c.4346G>A p.R1449H | Missense Mutation (SNP) | VAF 109/404 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs1472537135, COSV60810026; called by muse, mutect2, varscan2
- CACNA2D2 | c.993G>A p.S331= | Splice Region (SNP) | VAF 40/151 reads (26%) | catalogued as rs780661542, COSV56568964; called by muse, mutect2, varscan2
- CACNA2D3 | c.3209C>T p.A1070V | Missense Mutation (SNP) | VAF 22/102 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.035); catalogued as rs186910104; called by muse, mutect2, varscan2
- CAD | c.6190C>T p.R2064C | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53023698, COSV53029560; called by muse, mutect2, varscan2
- CADPS | c.2876G>A p.R959H | Missense Mutation (SNP) | VAF 23/86 reads (27%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.791); catalogued as rs376315928; called by muse, mutect2, varscan2
- CAPN5 | c.1616G>A p.R539H (on ENST00000456580; = p.R499H on NM_004055.5) | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT tolerated (0.34); PolyPhen benign (0.014); catalogued as rs140490506; called by muse, mutect2, varscan2
- CAPS2 | c.919C>T p.R307C | Missense Mutation (SNP) | VAF 30/121 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.058); catalogued as rs542643144, COSV60828898; called by muse, mutect2, varscan2
- CARD11 | c.2062C>T p.R688* | Nonsense Mutation (SNP) | VAF 4/22 reads (18%) | catalogued as COSV62754868; called by mutect2, varscan2
- CASKIN1 | c.586G>A p.A196T | Missense Mutation (SNP) | VAF 61/287 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV58876697; called by muse, mutect2, varscan2
- CASP10 | c.325C>T p.R109* | Nonsense Mutation (SNP) | VAF 8/28 reads (29%) | catalogued as rs201601111, COSV53779333, COSV99629116; called by muse, mutect2, varscan2
- CATSPER1 | c.128A>G p.Y43C | Missense Mutation (SNP) | VAF 34/374 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0.187); catalogued as COSV100376114; called by muse, mutect2
- CBL | c.1637C>T p.P546L | Missense Mutation (SNP) | VAF 37/133 reads (28%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.998); catalogued as rs751274314, COSV50662491; called by muse, mutect2, varscan2
- CBX4 | c.685C>A p.P229T | Missense Mutation (SNP) | VAF 45/173 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0.074); catalogued as COSV53967558; called by muse, mutect2, varscan2
- CCDC130 | c.845C>T p.A282V | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs747500355, COSV50005482; called by muse, mutect2, varscan2
- CCDC167 | c.290T>C p.M97T | Missense Mutation (SNP) | VAF 67/261 reads (26%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs764902665, COSV64982828; called by muse, mutect2, varscan2
- CCDC181 | c.1265del p.K422Sfs*6 (on ENST00000367806 / NM_001300969.1; = p.K421Sfs*6 on NM_021179.2) | Frame Shift Del (DEL) | VAF 24/118 reads (20%) | catalogued as rs759258977; called by mutect2, varscan2
- CCDC30 | c.1706G>A p.R569Q (on ENST00000340612; = p.R526Q on NM_001080850.3) | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.875); catalogued as rs774841907, COSV59604562; called by muse, mutect2, varscan2
- CCDC40 | c.2962C>T p.R988C | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.732); catalogued as rs757374609, COSV100884234, COSV66478614; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CCDC88A | c.3110C>T p.T1037M | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); catalogued as rs376732011; called by muse, mutect2, varscan2
- CCR7 | c.620C>T p.A207V | Missense Mutation (SNP) | VAF 41/120 reads (34%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs141181444, COSV55850487; called by muse, mutect2, varscan2
- CCT8L2 | c.773C>T p.T258M | Missense Mutation (SNP) | VAF 44/200 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as rs147789853, CM142324; called by muse, mutect2, varscan2
- CD163 | c.3239G>A p.R1080Q | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs750296031, COSV63131574; called by muse, mutect2, varscan2
- CD300LG | c.880C>T p.R294C | Missense Mutation (SNP) | VAF 29/117 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.183); catalogued as rs368815612; called by muse, mutect2, varscan2
- CD6 | c.1418C>T p.P473L | Missense Mutation (SNP) | VAF 61/290 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs778444894, COSV57842489; called by muse, mutect2, varscan2
- CDCA2 | c.269G>A p.R90H | Missense Mutation (SNP) | VAF 26/241 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99648536; called by muse, mutect2, varscan2
- CDCA7L | c.166-1G>A p.X56_splice | Splice Site (SNP) | VAF 34/123 reads (28%) | catalogued as COSV62261472; called by muse, mutect2, varscan2
- CDH23 | c.3191C>T p.A1064V | Missense Mutation (SNP) | VAF 91/168 reads (54%) | SIFT tolerated (0.05); PolyPhen benign (0.012); catalogued as COSV54951745; called by muse, mutect2, varscan2
- CDH23 | c.4973A>G p.Q1658R | Missense Mutation (SNP) | VAF 30/152 reads (20%) | SIFT tolerated (0.86); PolyPhen benign (0.003); catalogued as COSV56488403; called by muse, mutect2, varscan2
- CDH6 | c.2102G>A p.R701Q | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.971); catalogued as rs757234769, COSV54068487; called by muse, mutect2, varscan2
- CDK5 | c.808A>G p.N270D | Missense Mutation (SNP) | VAF 13/318 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.024); catalogued as COSV99877184; called by muse, mutect2
- CDKL5 | c.728G>T p.R243L | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.999); catalogued as COSV66110154; called by muse, mutect2
- CELSR1 | c.3512C>T p.P1171L | Missense Mutation (SNP) | VAF 12/119 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); catalogued as rs1297948385, COSV99419150; called by muse, mutect2
- CELSR2 | c.7360T>G p.F2454V | Missense Mutation (SNP) | VAF 25/362 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs574709737, COSV99604402; called by muse, mutect2
- CELSR3 | c.9167C>T p.T3056M | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.791); catalogued as rs759205227, COSV51038812; called by muse, mutect2, varscan2
- CENPU | c.48C>T p.G16= | Splice Region (SNP) | VAF 42/174 reads (24%) | catalogued as rs374369387; called by muse, mutect2, varscan2
- CEP192 | c.2471C>T p.P824L | Missense Mutation (SNP) | VAF 22/129 reads (17%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs780716624, COSV58060886; called by muse, mutect2, varscan2
- CEP290 | c.6334C>T p.R2112W | Missense Mutation (SNP) | VAF 29/94 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs1370883149, COSV58349175; called by muse, mutect2, varscan2
- CFAP58 | c.1331G>A p.R444Q | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT tolerated (0.09); PolyPhen benign (0.033); catalogued as rs145473772, COSV100458881; called by muse, mutect2, varscan2
- CHAF1A | c.2095G>A p.D699N | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.519); catalogued as rs375548057; called by muse, mutect2, varscan2
- CHD3 | c.5089C>T p.R1697* (on ENST00000330494 / NM_001005273.3; = p.R1663* on NM_005852.4) | Nonsense Mutation (SNP) | VAF 40/156 reads (26%) | catalogued as rs750291304, COSV57879885; called by muse, mutect2, varscan2
- CHD6 | c.7515G>A p.M2505I | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.006); catalogued as COSV64694242; called by muse, mutect2, varscan2
- CHD8 | c.5335C>T p.R1779C (on ENST00000646647 / NM_001170629.2; = p.R1500C on NM_020920.4) | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.872); catalogued as rs1367453709, COSV63037192; called by muse, mutect2, varscan2
- CHFR | c.703C>A p.P235T (on ENST00000432561 / NM_001161345.1; = p.P194T on NM_018223.2) | Missense Mutation (SNP) | VAF 130/465 reads (28%) | SIFT tolerated (0.28); PolyPhen benign (0.005); catalogued as rs1366834805, COSV57177813; called by muse, mutect2, varscan2
- CHIA | c.134A>G p.N45S | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.345); catalogued as COSV58478143; called by muse, mutect2, varscan2
- CHMP6 | c.389C>T p.T130M | Missense Mutation (SNP) | VAF 28/132 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs751560399, COSV57328008; called by muse, mutect2, varscan2
- CIC | c.683G>A p.R228Q | Missense Mutation (SNP) | VAF 43/146 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV50547102; called by muse, mutect2, varscan2
- CILP | c.3100C>T p.R1034C | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.38); catalogued as rs746992209, COSV56022019; called by muse, mutect2, varscan2
- CLASP2 | c.1490T>A p.I497N | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV56293475; called by muse, mutect2, varscan2
- CLCN2 | c.2507G>A p.R836Q | Missense Mutation (SNP) | VAF 48/146 reads (33%) | SIFT tolerated (0.52); PolyPhen probably damaging (0.999); catalogued as rs771316539, COSV55604171; called by muse, mutect2, varscan2
- CLCN4 | c.1309G>A p.G437S | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.284); catalogued as rs375397634, COSV101073930; called by muse, mutect2
- CLCN7 | c.1672G>A p.G558R | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1180615464, COSV51971734; called by muse, mutect2, varscan2
- CLDN10 | c.79A>G p.T27A | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.257); catalogued as COSV54826184; called by muse, mutect2, varscan2
- CLIP4 | c.718G>A p.A240T | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs748855460, COSV60752601; called by muse, mutect2, varscan2
- CLN5 | c.176G>A p.R59H | Missense Mutation (SNP) | VAF 25/220 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.567); catalogued as rs753197537, COSV66284924; called by muse, mutect2, varscan2
- CLPP | c.352T>A p.Y118N | Missense Mutation (SNP) | VAF 51/290 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55537313; called by muse, mutect2, varscan2
- CMTR1 | c.1276C>T p.R426* | Nonsense Mutation (SNP) | VAF 50/202 reads (25%) | catalogued as rs771545316, COSV65091661; called by muse, mutect2, varscan2
- CNOT3 | c.1694T>C p.L565P | Missense Mutation (SNP) | VAF 24/101 reads (24%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.995); catalogued as COSV55368311; called by muse, mutect2, varscan2
- CNPPD1 | c.1207C>A p.L403I | Missense Mutation (SNP) | VAF 45/235 reads (19%) | SIFT tolerated, low confidence (0.94); PolyPhen benign (0.1); catalogued as COSV55409447; called by muse, mutect2, varscan2
- CNTN6 | c.1253del p.K418Sfs*63 | Frame Shift Del (DEL) | VAF 7/28 reads (25%) | catalogued as rs758676375; called by mutect2, varscan2
- CNTRL | c.5438C>A p.A1813E | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.075); catalogued as rs765381326, COSV53053335; called by muse, mutect2, varscan2
- COBL | c.3203A>G p.E1068G | Missense Mutation (SNP) | VAF 16/321 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.272); catalogued as COSV99473420; called by muse, mutect2
- COL18A1 | c.1435G>A p.V479I (on ENST00000359759 / NM_130444.3; = p.V244I on NM_030582.4) | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT tolerated (0.45); PolyPhen benign (0.005); catalogued as rs532978021, COSV62702400; called by muse, mutect2, varscan2
- COL19A1 | c.2719A>T p.R907* | Nonsense Mutation (SNP) | VAF 57/215 reads (27%) | catalogued as COSV59587390; called by muse, mutect2, varscan2
- COL22A1 | c.1919C>T p.A640V | Missense Mutation (SNP) | VAF 38/123 reads (31%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as rs781455689, COSV57334559, COSV57359426; called by muse, mutect2, varscan2
- COL27A1 | c.424C>T p.R142W | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs768434921, COSV61930568; called by muse, mutect2, varscan2
- COL27A1 | c.3064G>A p.V1022M | Missense Mutation (SNP) | VAF 24/112 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.143); catalogued as rs141446597; called by muse, mutect2, varscan2
- COL5A2 | c.2229+2T>C p.X743_splice | Splice Site (SNP) | VAF 27/72 reads (38%) | catalogued as COSV66414910; called by muse, mutect2, varscan2
- COLGALT1 | c.1448G>A p.R483H | Missense Mutation (SNP) | VAF 24/108 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.009); catalogued as rs780452836, COSV53111471; called by muse, varscan2
- COPB1 | c.2394A>G p.I798M | Missense Mutation (SNP) | VAF 36/117 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV51450757; called by muse, mutect2, varscan2
- COPG1 | c.373G>A p.V125M | Missense Mutation (SNP) | VAF 32/101 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.675); catalogued as rs770080152, COSV59115449; called by muse, mutect2, varscan2
- CORO7 | c.2767G>A p.E923K | Missense Mutation (SNP) | VAF 7/176 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs201397239; called by muse, mutect2
- CPB1 | c.455G>A p.R152H | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.89); catalogued as rs760474959, COSV51571965; called by muse, mutect2, varscan2
- CPNE6 | c.433G>A p.E145K | Missense Mutation (SNP) | VAF 32/212 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.948); catalogued as rs756024652, COSV53746424; called by muse, mutect2, varscan2
- CPOX | c.727G>A p.V243M | Missense Mutation (SNP) | VAF 35/216 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs751673143, COSV51638097; called by muse, mutect2, varscan2
- CRACDL | c.2191G>A p.G731R | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.99); catalogued as COSV67410074; called by muse, mutect2, varscan2
- CREB3L2 | c.668G>A p.R223H | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.374); catalogued as rs1034111296, COSV57799964; called by muse, mutect2, varscan2
- CRTC2 | c.967A>G p.M323V | Missense Mutation (SNP) | VAF 43/149 reads (29%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as rs764333945, COSV57845576; called by muse, mutect2, varscan2
- CSF3R | c.2333C>T p.A778V | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.113); catalogued as rs759549054, COSV58963903; called by muse, mutect2, varscan2
- CSTF2T | c.1013G>A p.R338H | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as rs1252256298, COSV58656288; called by mutect2, varscan2
- CTDSP1 | c.598C>T p.R200W | Missense Mutation (SNP) | VAF 53/200 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs767602823, COSV56090683; called by muse, mutect2, varscan2
- CTNND2 | c.2054C>T p.A685V | Missense Mutation (SNP) | VAF 22/83 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as rs769088810, COSV100475052, COSV58893685; called by muse, mutect2, varscan2
- CUX2 | c.3854G>A p.S1285N | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.003); catalogued as COSV55647196; called by muse, mutect2, varscan2
- CYB5D2 | c.259G>A p.A87T | Missense Mutation (SNP) | VAF 25/142 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1197999512, COSV56802064; called by muse, mutect2, varscan2
- CYP1A2 | c.302A>G p.Q101R | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.208); catalogued as COSV59660996; called by muse, mutect2, varscan2
- CYP27A1 | c.1263C>T p.N421= | Splice Region (SNP) | VAF 26/111 reads (23%) | catalogued as rs748358246, COSV51470130; called by muse, mutect2, varscan2
- CYP2B6 | c.758G>A p.R253H | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.075); catalogued as rs373086625, COSV57844907; called by muse, mutect2, varscan2
- DAGLA | c.1612C>T p.R538C | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99944553; called by muse, mutect2
- DBN1 | c.821C>T p.S274L | Missense Mutation (SNP) | VAF 121/537 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1165123989, COSV52788825, COSV52792976; called by muse, mutect2, varscan2
- DCAF4L1 | c.704C>T p.T235M | Missense Mutation (SNP) | VAF 18/280 reads (6%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV60786836; called by muse, mutect2
- DCLRE1A | c.374G>A p.C125Y | Missense Mutation (SNP) | VAF 19/229 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100800434; called by muse, mutect2
- DCTN1 | c.3758C>T p.A1253V | Missense Mutation (SNP) | VAF 17/110 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0.012); catalogued as rs1026036256, COSV62621459; called by muse, mutect2, varscan2
- DCTN1 | c.3517C>T p.R1173C | Missense Mutation (SNP) | VAF 48/223 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.18); catalogued as rs1442881228, COSV62621462; called by muse, varscan2
- DDHD1 | c.1117C>T p.R373* (on ENST00000323669; = p.R570* on NM_030637.3) | Nonsense Mutation (SNP) | VAF 18/106 reads (17%) | catalogued as COSV60362577; called by muse, mutect2, varscan2
- DDX49 | c.535C>T p.R179C | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as rs771078768, COSV53232353; called by muse, mutect2, varscan2
- DDX58 | c.77T>C p.L26P | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.961); catalogued as COSV101153073; called by mutect2, varscan2
- DEFB124 | c.139C>A p.L47M | Missense Mutation (SNP) | VAF 62/335 reads (19%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.273); catalogued as COSV58343641; called by muse, mutect2, varscan2
- DENND2B | c.2080C>T p.R694W | Missense Mutation (SNP) | VAF 34/144 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs75648256, COSV100567532, COSV58207678; called by muse, mutect2, varscan2
- DENND4B | c.4420C>T p.R1474W | Missense Mutation (SNP) | VAF 42/192 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.018); catalogued as rs922096092, COSV63411827; called by muse, mutect2, varscan2
- DES | c.937G>A p.A313T | Missense Mutation (SNP) | VAF 55/171 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.941); catalogued as rs766252091, COSV64661015; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DGCR8 | c.125C>T p.T42M | Missense Mutation (SNP) | VAF 27/85 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.886); catalogued as rs1245517093, COSV61228617; called by muse, mutect2, varscan2
- DGKD | c.1117C>T p.R373W (on ENST00000264057 / NM_152879.3; = p.R329W on NM_003648.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 82/518 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1381673350, COSV51102344; called by muse, mutect2, varscan2
- DGKK | c.1331G>A p.R444Q | Missense Mutation (SNP) | VAF 6/79 reads (8%) | SIFT tolerated (0.82); PolyPhen benign (0.25); catalogued as COSV101053008; called by muse, mutect2
- DGKZ | c.1391C>T p.P464L (on ENST00000454345 / NM_001105540.2; = p.P276L on NM_003646.4) | Missense Mutation (SNP) | VAF 21/97 reads (22%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV58994802; called by muse, mutect2, varscan2
- DHX16 | c.2771G>A p.R924H | Missense Mutation (SNP) | VAF 26/125 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs778406014, COSV53315972; called by muse, mutect2, varscan2
- DICER1 | c.94T>C p.W32R | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV58627842; called by muse, mutect2, varscan2
- DIP2C | c.2128G>T p.G710* | Nonsense Mutation (SNP) | VAF 26/111 reads (23%) | catalogued as COSV55178216; called by muse, mutect2, varscan2
- DIRAS1 | c.509G>A p.R170H | Missense Mutation (SNP) | VAF 18/89 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV60216631; called by muse, mutect2, varscan2
- DISP3 | c.2812G>A p.A938T | Missense Mutation (SNP) | VAF 25/98 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.464); catalogued as rs759615246, COSV53821020; called by muse, mutect2, varscan2
- DLL4 | c.1001G>A p.R334H | Missense Mutation (SNP) | VAF 42/185 reads (23%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.927); catalogued as rs781059377, COSV51060900; called by muse, mutect2, varscan2
- DMXL1 | c.7805A>G p.E2602G | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.543); catalogued as COSV60720405; called by muse, mutect2, varscan2
- DMXL2 | c.187G>T p.V63L | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.978); catalogued as COSV51855745; called by muse, mutect2, varscan2
- DNAH1 | c.4603C>T p.R1535C | Missense Mutation (SNP) | VAF 72/341 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.393); catalogued as rs775222435, COSV70228628, COSV70235959; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNAH1 | c.8393G>A p.R2798H | Missense Mutation (SNP) | VAF 27/171 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as rs747814703, COSV70235968; called by muse, mutect2, varscan2
- DNAH10 | c.9319C>T p.R3107C (on ENST00000409039; = p.R3046C on NM_207437.3) | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1380037462, COSV101292457; called by muse, mutect2
- DNAH11 | c.10055C>T p.T3352M | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs369182142; called by muse, mutect2, varscan2
- DNAH2 | c.9872C>T p.A3291V | Missense Mutation (SNP) | VAF 60/208 reads (29%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as rs770700071, COSV66726805; called by muse, mutect2, varscan2
- DNAH8 | c.4418del p.N1473Ifs*15 | Frame Shift Del (DEL) | VAF 8/38 reads (21%) | catalogued as rs778628413, COSV59486260; called by mutect2, varscan2
- DNAH9 | c.2129T>C p.L710P | Missense Mutation (SNP) | VAF 24/112 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52375660; called by muse, mutect2, varscan2
- DNAJB5 | c.983G>A p.R328H | Missense Mutation (SNP) | VAF 47/152 reads (31%) | SIFT tolerated (0.37); PolyPhen benign (0.013); catalogued as rs745724497, COSV56627384; called by muse, mutect2, varscan2
- DNAJC14 | c.1127G>A p.R376H | Missense Mutation (SNP) | VAF 29/121 reads (24%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs201520030, COSV57914304; called by muse, mutect2, varscan2
- DOCK8 | c.959C>T p.T320M | Missense Mutation (SNP) | VAF 24/91 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.189); catalogued as rs766320232, COSV66635990; called by muse, mutect2, varscan2
- DOK5 | c.202G>A p.V68I | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs200557118, COSV52825434; called by muse, mutect2, varscan2
- DST | c.1130G>A p.R377H | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs566628404, COSV55038785; called by muse, mutect2, varscan2
- DUSP3 | c.473G>A p.R158H | Missense Mutation (SNP) | VAF 27/120 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1460408962, COSV56825531; called by muse, mutect2, varscan2
- DVL3 | c.202C>T p.P68S | Missense Mutation (SNP) | VAF 100/367 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV57458259; called by muse, mutect2, varscan2
- DYNC1LI2 | c.1189C>T p.R397W | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs778487216, COSV50756467; called by muse, mutect2, varscan2
- EARS2 | c.221G>T p.R74M | Missense Mutation (SNP) | VAF 13/140 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99563384; called by muse, mutect2
- EEA1 | c.730C>T p.R244C | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as rs749198752, COSV59289742; called by muse, mutect2, varscan2
- EFNB3 | c.259G>A p.A87T | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.114); catalogued as COSV56834832; called by muse, mutect2, varscan2
- EGR2 | c.1048C>T p.R350W | Missense Mutation (SNP) | VAF 50/173 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV54348817; called by muse, mutect2, varscan2
- EHD2 | c.1094C>T p.A365V | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as rs1054930244, COSV54412007; called by muse, mutect2
- EHMT1 | c.1160G>A p.R387H | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0); catalogued as rs776502547, COSV58370223; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EIF2AK3 | c.1306C>T p.H436Y | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.701); catalogued as rs761048614, COSV57550417; called by muse, mutect2, varscan2
- ELAC2 | c.905C>A p.P302H | Missense Mutation (SNP) | VAF 55/210 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV62034658; called by muse, mutect2, varscan2
- ELN | c.1339G>A p.A447T | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT tolerated, low confidence (0.21); PolyPhen probably damaging (0.99); catalogued as rs139335797; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ELOA2 | c.1345G>A p.A449T | Missense Mutation (SNP) | VAF 32/101 reads (32%) | SIFT tolerated (0.22); PolyPhen benign (0.01); catalogued as COSV55310972; called by muse, mutect2, varscan2
- ELOVL4 | c.478T>C p.Y160H | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100876360; called by muse, mutect2, varscan2
- EML1 | c.2437C>T p.R813C | Missense Mutation (SNP) | VAF 45/178 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs772174519, COSV51746088; called by muse, mutect2, varscan2
- EML2 | c.886G>A p.G296S | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT tolerated (1); PolyPhen possibly damaging (0.872); catalogued as rs757830511, COSV55603746; called by muse, mutect2, varscan2
- ENDOV | c.353T>G p.L118R | Missense Mutation (SNP) | VAF 28/123 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as COSV60499057; called by muse, mutect2, varscan2
- EP400 | c.3025G>A p.E1009K | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.127); catalogued as rs150705036; called by muse, mutect2, varscan2
- EPB41L1 | c.397C>A p.L133I | Missense Mutation (SNP) | VAF 19/101 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52444345; called by muse, mutect2, varscan2
- EPB42 | c.734G>A p.R245H (on ENST00000441366 / NM_001114134.2; = p.R275H on NM_000119.3) | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.912); catalogued as rs1242502706, COSV55751593; called by muse, mutect2, varscan2
- EPHB4 | c.913C>T p.R305C | Missense Mutation (SNP) | VAF 11/148 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); catalogued as rs1562972261, COSV100639578, COSV62270797; called by muse, mutect2
- ERCC6 | c.4211G>A p.R1404H | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.451); catalogued as rs755854972, COSV63388057; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ERRFI1 | c.34A>G p.R12G | Missense Mutation (SNP) | VAF 28/146 reads (19%) | SIFT tolerated (0.68); PolyPhen possibly damaging (0.721); catalogued as COSV66311292; called by muse, mutect2, varscan2
- ESF1 | c.2149G>A p.E717K | Missense Mutation (SNP) | VAF 53/175 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.746); catalogued as rs1156518434, COSV52518883; called by muse, mutect2, varscan2
- ETNPPL | c.400A>G p.T134A | Missense Mutation (SNP) | VAF 25/122 reads (20%) | SIFT tolerated (0.25); PolyPhen benign (0.34); catalogued as rs760475668, COSV56597467; called by muse, mutect2, varscan2
- EVI5L | c.138-1G>T p.X46_splice | Splice Site (SNP) | VAF 14/67 reads (21%) | catalogued as COSV54488597; called by muse, mutect2, varscan2
- EVI5L | c.544G>A p.V182I | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs745770179, CM142390, COSV54488609; called by muse, mutect2, varscan2
- EVPL | c.4238G>A p.R1413Q | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.009); catalogued as rs900135611, COSV100044743, COSV56915543; called by muse, mutect2, varscan2
- EXOC4 | c.2464A>G p.S822G | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.013); catalogued as rs767913030, COSV54121586; called by muse, mutect2, varscan2
- EXOC6B | c.2407C>T p.R803* | Nonsense Mutation (SNP) | VAF 18/123 reads (15%) | catalogued as rs369498012; called by muse, mutect2, varscan2
- F9 | c.1180A>C p.M394L | Missense Mutation (SNP) | VAF 43/132 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as CD125319, CM940678, COSV54382320; called by muse, mutect2, varscan2
- FAM120C | c.2042G>A p.R681Q | Missense Mutation (SNP) | VAF 8/146 reads (5%) | SIFT tolerated (0.13); PolyPhen benign (0.059); catalogued as rs782171345; called by muse, mutect2
- FAM160A2 | c.2908C>A p.L970I (on ENST00000449352 / NM_001098794.2; = p.L984I on NM_032127.4) | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.046); catalogued as COSV56414624, COSV56415370; called by muse, mutect2, varscan2
- FAM161B | c.722C>T p.T241M (on ENST00000651776; = p.T178M on NM_152445.3) | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.592); catalogued as rs374300499; called by muse, mutect2, varscan2
- FAM200A | c.1553T>C p.L518P | Missense Mutation (SNP) | VAF 14/354 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV101282735; called by muse, mutect2
- FAM20A | c.1532G>T p.G511V | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.096); catalogued as COSV56838261; called by muse, mutect2
- FAM221B | c.611G>A p.R204H | Missense Mutation (SNP) | VAF 64/245 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs781726259, COSV65073620, COSV65075034; called by muse, mutect2, varscan2
- FAM47A | c.1235G>A p.R412H | Missense Mutation (SNP) | VAF 53/180 reads (29%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.735); catalogued as rs371474916, COSV60496032; called by muse, mutect2, varscan2
- FASN | c.4973C>T p.A1658V | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.43); catalogued as rs569723911, COSV60760799; called by muse, mutect2, varscan2
- FAT1 | c.10315G>A p.V3439I | Missense Mutation (SNP) | VAF 31/109 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs201982861, COSV71675930, COSV71676690; called by muse, mutect2, varscan2
- FBN1 | c.6170G>A p.R2057Q | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs181032147, CM972817, COSV57329628; called by muse, mutect2, varscan2
- FBXL14 | c.1001C>T p.T334M | Missense Mutation (SNP) | VAF 45/191 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV59337517; called by muse, mutect2, varscan2
- FBXL6 | c.1493C>T p.P498L | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.11); catalogued as rs782380191, COSV57353433; called by muse, mutect2, varscan2
- FBXW10 | c.1142C>T p.T381I | Missense Mutation (SNP) | VAF 45/231 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.312); catalogued as COSV57322130; called by muse, mutect2, varscan2
- FBXW10 | c.1573G>T p.G525W | Missense Mutation (SNP) | VAF 15/337 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100111592; called by muse, mutect2
- FCGR1A | c.706C>A p.L236M | Missense Mutation (SNP) | VAF 55/244 reads (23%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.767); catalogued as COSV64986060; called by muse, mutect2, varscan2
- FCRL1 | c.1196T>C p.L399P | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV63827353; called by muse, mutect2, varscan2
- FGFR4 | c.1251+4C>T | Splice Region (SNP) | VAF 8/61 reads (13%) | catalogued as COSV52809631; called by muse, mutect2, varscan2
- FGFRL1 | c.233G>A p.R78H | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.33); catalogued as rs763867368, COSV53259370; called by muse, mutect2, varscan2
- FIGN | c.643C>T p.H215Y | Missense Mutation (SNP) | VAF 15/106 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.61); catalogued as COSV60771629; called by muse, mutect2, varscan2
- FKBP9 | c.1433C>T p.A478V | Missense Mutation (SNP) | VAF 16/308 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.017); catalogued as COSV99640132; called by muse, mutect2
- FLG | c.5740C>T p.Q1914* | Nonsense Mutation (SNP) | VAF 88/433 reads (20%) | catalogued as rs777116132, COSV64248549; called by muse, mutect2, varscan2
- FLI1 | c.1306G>A p.V436I | Missense Mutation (SNP) | VAF 40/152 reads (26%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.475); catalogued as rs764743895, COSV55642567; called by muse, mutect2, varscan2
- FMNL1 | c.3239G>A p.R1080H | Missense Mutation (SNP) | VAF 47/189 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.943); catalogued as rs761421986, COSV58959073; called by muse, mutect2, varscan2
- FMR1 | c.1594C>T p.R532W | Missense Mutation (SNP) | VAF 31/129 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.93); catalogued as COSV54427298; called by muse, mutect2, varscan2
- FOXD4 | c.1148C>T p.A383V | Missense Mutation (SNP) | VAF 27/248 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs1231318195, COSV58702806; called by muse, mutect2, varscan2
- FREM1 | c.34G>A p.V12M | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs199906654, COSV66527274; called by muse, mutect2, varscan2
- FREM2 | c.4310T>C p.V1437A | Missense Mutation (SNP) | VAF 26/126 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.011); catalogued as COSV54851655; called by muse, mutect2, varscan2
- FRMD5 | c.1657A>G p.R553G | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV68725310; called by muse, mutect2, varscan2
- FSCN1 | c.947C>T p.T316M | Missense Mutation (SNP) | VAF 16/91 reads (18%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.993); catalogued as rs143738037; called by muse, mutect2, varscan2
- FUT1 | c.196G>A p.A66T | Missense Mutation (SNP) | VAF 27/112 reads (24%) | SIFT tolerated (0.75); PolyPhen benign (0.006); catalogued as rs144689580; called by muse, mutect2, varscan2
- FUT10 | c.46G>A p.V16I | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs368379310, COSV59451060; called by muse, mutect2, varscan2
- FXN | c.257G>T p.S86I (on ENST00000377270; = p.S161I on NM_000144.5) | Missense Mutation (SNP) | VAF 43/264 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV66010483; called by muse, mutect2, varscan2
- FZD10 | c.635C>T p.T212M | Missense Mutation (SNP) | VAF 33/105 reads (31%) | SIFT tolerated (0.27); PolyPhen benign (0.416); catalogued as COSV57475777; called by muse, mutect2, varscan2
- GABRB2 | c.577C>T p.R193C | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.418); catalogued as rs193920932, COSV50906596; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GALNT13 | c.1462A>G p.N488D | Missense Mutation (SNP) | VAF 6/87 reads (7%) | SIFT tolerated (0.72); PolyPhen benign (0.001); catalogued as COSV101223708; called by muse, mutect2
- GAPDH | c.283G>A p.V95I | Missense Mutation (SNP) | VAF 39/209 reads (19%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.007); catalogued as rs371192512, COSV57522039; called by muse, mutect2, varscan2
- GARNL3 | c.740C>T p.T247M | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.759); catalogued as rs768627583, COSV59229385; called by muse, mutect2, varscan2
- GASK1B | c.970A>G p.T324A | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated (0.29); PolyPhen benign (0.027); catalogued as COSV56711672; called by muse, mutect2, varscan2
- GATA1 | c.739C>T p.R247C | Missense Mutation (SNP) | VAF 30/115 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs782126313, COSV64961355; called by muse, mutect2, varscan2
- GBA | c.121C>T p.R41C | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.012); catalogued as rs190207858, COSV59170823; called by muse, mutect2, varscan2
- GDF5 | c.1273G>A p.E425K | Missense Mutation (SNP) | VAF 38/196 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs755107659, COSV65503502; called by muse, mutect2, varscan2
- GDPD4 | c.1282G>A p.V428I | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as rs762493323, COSV60022831; called by muse, mutect2, varscan2
- GFM2 | c.1561G>A p.V521M | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); catalogued as COSV57190089, COSV57193306; called by muse, mutect2, varscan2
- GFOD2 | c.313C>T p.R105W | Missense Mutation (SNP) | VAF 30/99 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs552516505, COSV52059761; called by muse, mutect2, varscan2
- GH2 | c.626G>A p.R209H | Missense Mutation (SNP) | VAF 61/330 reads (18%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs773390813, COSV60427069; called by muse, mutect2, varscan2
- GIPC1 | c.476G>A p.R159H | Missense Mutation (SNP) | VAF 33/132 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.132); catalogued as rs762937627, COSV100600057, COSV61774660; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GK2 | c.490G>A p.V164I | Missense Mutation (SNP) | VAF 54/215 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.078); catalogued as COSV62626645; called by muse, mutect2, varscan2
- GLB1L3 | c.1411G>A p.A471T | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.03); catalogued as rs778132907, COSV68393417; called by muse, mutect2, varscan2
- GLIS1 | c.1613C>T p.A538V | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT tolerated (0.5); PolyPhen benign (0.006); catalogued as rs1270954254, COSV56555940; called by muse, mutect2, varscan2
- GLS2 | c.1430G>A p.R477H | Missense Mutation (SNP) | VAF 50/233 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.783); catalogued as rs981808916, COSV57666036; called by muse, mutect2, varscan2
- GNAS | c.563C>T p.A188V | Missense Mutation (SNP) | VAF 36/129 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV55687163; called by muse, mutect2, varscan2
- GNB1L | c.811G>A p.A271T | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.994); catalogued as rs149398894; called by muse, mutect2, varscan2
- GPI | c.242G>A p.R81Q | Missense Mutation (SNP) | VAF 45/195 reads (23%) | SIFT tolerated, low confidence (0.3); PolyPhen possibly damaging (0.447); catalogued as rs575607644, COSV62894873; called by muse, mutect2, varscan2
- GRAMD4 | c.1247C>T p.T416M | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.563); catalogued as rs138805326; called by muse, mutect2, varscan2
- GRIA2 | c.666G>T p.Q222H | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.955); catalogued as COSV52405304; called by muse, mutect2, varscan2
- GRIP2 | c.814C>T p.P272S (on ENST00000619221; = p.P175S on NM_001080423.4) | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV56124714; called by mutect2, varscan2
- GRM4 | c.874C>T p.R292C | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.828); catalogued as rs561760325, COSV65219333; called by muse, mutect2, varscan2
- GSTZ1 | c.58G>A p.V20I | Missense Mutation (SNP) | VAF 40/212 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as COSV53624547; called by muse, mutect2, varscan2
- GTF3C1 | c.1264C>T p.R422W | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1301799383, COSV62241823; called by muse, mutect2, varscan2
- GYS1 | c.2054G>A p.R685Q | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.097); catalogued as rs1490178936, COSV54405254; called by muse, mutect2, varscan2
- H2AW | c.13G>T p.G5C | Missense Mutation (SNP) | VAF 4/63 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.057); catalogued as COSV64209709; called by muse, mutect2
- HAS2 | c.464A>G p.K155R | Missense Mutation (SNP) | VAF 41/159 reads (26%) | SIFT tolerated (0.52); PolyPhen benign (0.001); catalogued as COSV58267070; called by muse, mutect2, varscan2
- HDAC9 | c.511C>T p.R171C | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.928); catalogued as rs745896467, COSV101286878; called by muse, mutect2, varscan2
- HECTD1 | c.4670G>A p.R1557Q | Missense Mutation (SNP) | VAF 10/174 reads (6%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.921); catalogued as COSV101237438; called by muse, mutect2
- HECTD3 | c.2527C>T p.R843C | Missense Mutation (SNP) | VAF 26/105 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs1188887385, COSV100938152, COSV64670855; called by muse, mutect2, varscan2
- HECW2 | c.3383G>A p.R1128H | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as rs765861065, COSV53673701; called by muse, mutect2, varscan2
- HECW2 | c.1999C>T p.R667W | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.635); catalogued as rs1349476231, COSV53662448; called by muse, mutect2, varscan2
- HERC2 | c.6451C>T p.R2151C | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs200377671; called by muse, mutect2, varscan2
- HEXD | c.509C>T p.T170M | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT tolerated (0.24); PolyPhen benign (0.021); catalogued as rs749879786, COSV60066080; called by muse, mutect2, varscan2
- HFM1 | c.1304T>C p.V435A | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.509); catalogued as COSV54036834; called by muse, mutect2, varscan2
- HIC2 | c.196G>A p.A66T | Missense Mutation (SNP) | VAF 33/380 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.645); catalogued as COSV101335603; called by muse, mutect2
- HIP1R | c.2236C>T p.R746W | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.276); catalogued as rs760394973, COSV53444775; called by muse, mutect2, varscan2
- HIVEP2 | c.4112A>C p.E1371A | Missense Mutation (SNP) | VAF 7/93 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.095); catalogued as COSV99174656; called by muse, mutect2
- HMCN1 | c.9412C>T p.R3138W | Missense Mutation (SNP) | VAF 23/90 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs187753126, COSV54915178; called by muse, mutect2, varscan2
- HNRNPH2 | c.1229G>A p.G410D | Missense Mutation (SNP) | VAF 31/315 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.107); catalogued as COSV100347175; called by muse, mutect2
- HOOK2 | c.1348G>A p.A450T | Missense Mutation (SNP) | VAF 23/117 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1455714684, COSV53402078; called by muse, mutect2, varscan2
- HSDL1 | c.263C>T p.A88V | Missense Mutation (SNP) | VAF 37/127 reads (29%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.943); catalogued as rs150265492, COSV54740578; called by muse, mutect2, varscan2
- HSFX1 | c.239C>T p.P80L | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0.27); catalogued as rs1331090859; called by mutect2, varscan2
- HSPA9 | c.611C>A p.A204D | Missense Mutation (SNP) | VAF 31/143 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as COSV51866275; called by muse, mutect2, varscan2
- HSPB11 | c.110C>T p.T37M | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs769134105, COSV52042183; called by muse, mutect2
- HTR1B | c.728C>T p.T243M | Missense Mutation (SNP) | VAF 23/120 reads (19%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.939); catalogued as rs968574182, COSV64051119; called by muse, mutect2, varscan2
- HUNK | c.1985G>A p.R662Q | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); catalogued as rs772115970, COSV54226478; called by muse, mutect2, varscan2
- HUWE1 | c.12173C>T p.A4058V | Missense Mutation (SNP) | VAF 18/105 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); catalogued as COSV53363007; called by muse, mutect2, varscan2
- IBSP | c.769G>A p.V257I | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.045); catalogued as rs758115196, COSV56894829; called by muse, mutect2, varscan2
- ICE1 | c.3458C>T p.T1153M | Missense Mutation (SNP) | VAF 25/98 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs142087337, COSV56831953; called by muse, mutect2, varscan2
- ICE2 | c.1354A>G p.N452D | Missense Mutation (SNP) | VAF 32/86 reads (37%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs746264006, COSV55033915; called by muse, mutect2, varscan2
- IDH3B | c.1082G>A p.R361Q | Missense Mutation (SNP) | VAF 35/133 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0.187); catalogued as rs145651330; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- IDH3G | c.979G>A p.A327T | Missense Mutation (SNP) | VAF 121/553 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54209963; called by muse, mutect2, varscan2
- IFNGR2 | c.341G>A p.R114H | Missense Mutation (SNP) | VAF 33/137 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs772588714, COSV51641125; called by muse, mutect2, varscan2
- IGHE | c.992C>T p.T331M | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs368118853; called by muse, mutect2, varscan2
- IGHM | c.1402G>A p.V468I | Missense Mutation (SNP) | VAF 40/157 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.205); catalogued as rs772304630; called by muse, mutect2, varscan2
- IGSF1 | c.2713G>A p.A905T | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.995); catalogued as rs763768928, COSV63837299; called by muse, mutect2, varscan2
- IL10 | c.444G>A p.K148= | Splice Region (SNP) | VAF 15/72 reads (21%) | catalogued as COSV65594984; called by muse, mutect2, varscan2
- IL17RA | c.1349G>A p.G450D | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV60056160; called by muse, mutect2, varscan2
- IL1RL2 | c.641T>A p.V214E | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV51818725; called by muse, mutect2, varscan2
- IMPA2 | c.365T>C p.F122S | Missense Mutation (SNP) | VAF 67/216 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52321390; called by muse, mutect2, varscan2
- INO80D | c.1540del p.M514Wfs*5 | Frame Shift Del (DEL) | VAF 8/74 reads (11%) | catalogued as COSV68960008; called by mutect2, pindel, varscan2
- INPP5F | c.2699G>A p.R900Q | Missense Mutation (SNP) | VAF 61/106 reads (58%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as rs1287690887, COSV62823703; called by muse, mutect2, varscan2
- INPP5J | c.2264C>T p.A755V (on ENST00000331075 / NM_001284285.2; = p.A387V on NM_001002837.2) | Missense Mutation (SNP) | VAF 53/211 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs1432432121, COSV53212625; called by muse, mutect2, varscan2
- INPPL1 | c.2658C>T p.Y886= | Splice Region (SNP) | VAF 14/86 reads (16%) | catalogued as rs778488522, COSV53356067; called by muse, mutect2, varscan2
- ITGA9 | c.359G>A p.R120H | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs1474405958, COSV53252406; called by muse, mutect2, varscan2
- ITGAX | c.2114T>A p.V705D | Missense Mutation (SNP) | VAF 26/114 reads (23%) | SIFT tolerated (0.33); PolyPhen benign (0.014); catalogued as COSV51651253; called by muse, mutect2, varscan2
- ITIH1 | c.218G>A p.S73N | Missense Mutation (SNP) | VAF 12/180 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV99835442; called by muse, mutect2
- KALRN | c.937C>T p.R313W | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53753850; called by muse, mutect2, varscan2
- KCNA5 | c.1243C>T p.R415C | Missense Mutation (SNP) | VAF 61/242 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1286773038, COSV52908572; called by muse, mutect2, varscan2
- KCNH2 | c.1591C>T p.R531W | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs199472915, CM097443, COSV51226669; ClinVar: uncertain significance / not provided; called by muse, varscan2
- KCNJ5 | c.259C>T p.R87C | Missense Mutation (SNP) | VAF 53/212 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs781022847, COSV57963992; called by muse, mutect2, varscan2
- KCNK3 | c.524C>G p.A175G | Missense Mutation (SNP) | VAF 42/139 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.859); catalogued as COSV57191543; called by muse, mutect2, varscan2
- KCNK5 | c.1313C>T p.S438L | Missense Mutation (SNP) | VAF 21/100 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs915032034, COSV63989172; called by muse, mutect2, varscan2
- KCNT1 | c.323G>A p.C108Y (on ENST00000488444; = p.C127Y on NM_020822.3) | Missense Mutation (SNP) | VAF 27/110 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1299714104, COSV53710149; called by muse, mutect2, varscan2
- KCNV1 | c.997C>T p.R333C | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as rs1313499614, COSV52088317, COSV52088438; called by muse, mutect2
- KIAA0319L | c.28A>T p.N10Y | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.023); catalogued as COSV57850416; called by muse, mutect2, varscan2
- KIAA1614 | c.554C>T p.P185L | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as rs372280369; called by muse, mutect2, varscan2
- KIF13B | c.1253C>T p.T418M | Missense Mutation (SNP) | VAF 32/121 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs779216622, COSV73054633; called by muse, mutect2, varscan2
- KIF17 | c.1229G>A p.R410Q | Missense Mutation (SNP) | VAF 37/190 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.087); catalogued as rs373523975, COSV99929993; called by muse, mutect2, varscan2
- KIF1B | c.5324G>A p.R1775H (on ENST00000377086 / NM_001365952.1; = p.R1729H on NM_015074.3) | Missense Mutation (SNP) | VAF 39/152 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs374303355; ClinVar: uncertain significance; called by muse, mutect2
- KIF20B | c.5333G>A p.R1778Q (on ENST00000371728 / NM_001284259.2; = p.R1738Q on NM_016195.4) | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs146495295; called by muse, mutect2, varscan2
- KIF27 | c.475C>T p.R159* | Nonsense Mutation (SNP) | VAF 14/86 reads (16%) | catalogued as rs537684585, COSV52829732; called by muse, mutect2, varscan2
- KIF5A | c.514C>T p.R172C | Missense Mutation (SNP) | VAF 35/146 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1159429693, COSV54058927, COSV99672449; called by muse, mutect2, varscan2
- KLHDC3 | c.692C>T p.P231L | Missense Mutation (SNP) | VAF 49/196 reads (25%) | SIFT tolerated (0.34); PolyPhen benign (0.051); catalogued as rs763964077, COSV55065633, COSV55065807; called by muse, mutect2, varscan2
- KLHL38 | c.127C>T p.R43W | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0.022); catalogued as rs745493563, COSV100384290, COSV58088918; called by muse, mutect2, varscan2
- KLRC4 | c.171G>T p.K57N | Missense Mutation (SNP) | VAF 53/189 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.653); catalogued as COSV58672499; called by muse, mutect2, varscan2
- KMT2B | c.596G>A p.R199Q | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.968); catalogued as COSV52892460; called by muse, mutect2, varscan2
- KMT2B | c.2908C>T p.R970W | Missense Mutation (SNP) | VAF 27/95 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV55859180; called by muse, mutect2, varscan2
- KMT2B | c.4889A>G p.H1630R | Missense Mutation (SNP) | VAF 50/206 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55869042; called by muse, mutect2, varscan2
- KMT2B | c.8146T>C p.*2716Rext*47 | Nonstop Mutation (SNP) | VAF 28/128 reads (22%) | catalogued as COSV53076509; called by muse, mutect2, varscan2
- KMT2E | c.3298C>T p.R1100* | Nonsense Mutation (SNP) | VAF 9/65 reads (14%) | catalogued as COSV57576130, COSV57580158; called by muse, varscan2
- KPTN | c.529G>A p.E177K | Missense Mutation (SNP) | VAF 29/155 reads (19%) | SIFT tolerated (0.38); PolyPhen benign (0.057); catalogued as rs370974946; called by muse, mutect2, varscan2
- KREMEN1 | c.545C>T p.A182V (on ENST00000407188; = p.A184V on NM_032045.5) | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.011); catalogued as COSV59914751; called by muse, mutect2, varscan2
- KRT32 | c.1301G>A p.R434H | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs139528234; called by muse, mutect2, varscan2
- KRT35 | c.4G>A p.A2T | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.52); PolyPhen benign (0.007); catalogued as COSV55844501; called by muse, mutect2, varscan2
- KRT72 | c.892G>A p.E298K | Missense Mutation (SNP) | VAF 100/384 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.119); catalogued as rs752607357, COSV53376696; called by muse, mutect2, varscan2
- KRTAP19-1 | c.13G>A p.G5S | Missense Mutation (SNP) | VAF 13/120 reads (11%) | SIFT tolerated, low confidence (0.7); PolyPhen benign (0.266); catalogued as rs1231747765, COSV66861607; called by muse, mutect2, varscan2
- LAMB3 | c.2882G>A p.R961Q | Missense Mutation (SNP) | VAF 26/89 reads (29%) | SIFT tolerated (0.27); PolyPhen benign (0.006); catalogued as rs533449267, COSV50526140; called by muse, mutect2, varscan2
- LAMTOR5 | c.215G>A p.G72E (on ENST00000602318 / NM_001382293.1; = p.G154E on NM_006402.3) | Missense Mutation (SNP) | VAF 28/125 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.275); catalogued as COSV56678948; called by muse, mutect2, varscan2
- LCE1D | c.307G>A p.G103S | Missense Mutation (SNP) | VAF 16/27 reads (59%) | PolyPhen possibly damaging (0.659); catalogued as rs1468360393, COSV58270476; called by muse, varscan2
- LCT | c.2470G>A p.D824N | Missense Mutation (SNP) | VAF 45/159 reads (28%) | SIFT tolerated (0.2); PolyPhen benign (0.43); catalogued as rs140434720; called by muse, mutect2, varscan2
- LEF1 | c.745G>A p.G249S | Missense Mutation (SNP) | VAF 135/475 reads (28%) | SIFT tolerated (0.45); PolyPhen benign (0.079); catalogued as rs146861754; called by muse, mutect2, varscan2
- LHX9 | c.403C>T p.R135C | Missense Mutation (SNP) | VAF 15/95 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.632); catalogued as COSV100435659, COSV61331394; called by muse, mutect2, varscan2
- LIG1 | c.1670G>A p.R557H | Missense Mutation (SNP) | VAF 44/213 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs746737248, COSV54395876; called by muse, mutect2, varscan2
- LIMK2 | c.857G>A p.R286H | Missense Mutation (SNP) | VAF 29/140 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.109); catalogued as rs370892426; called by muse, mutect2, varscan2
- LMOD2 | c.208A>G p.M70V | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.46); PolyPhen probably damaging (0.968); catalogued as COSV71755843; called by muse, mutect2, varscan2
- LMTK3 | c.1094G>A p.R365H | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.984); catalogued as rs563664464, COSV54316954; called by muse, mutect2, varscan2
- LRP10 | c.1039G>A p.G347S | Missense Mutation (SNP) | VAF 17/103 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs760647527, COSV62078881; called by muse, mutect2, varscan2
- LRP1B | c.7745A>G p.D2582G | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67272337; called by muse, mutect2, varscan2
- LRRC45 | c.836C>T p.A279V | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as rs528261442, COSV60712913; called by muse, mutect2, varscan2
- LRRC6 | c.769A>G p.T257A | Missense Mutation (SNP) | VAF 51/212 reads (24%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.931); catalogued as COSV51547411; called by muse, mutect2, varscan2
- LRRC7 | c.1171C>T p.R391C (on ENST00000651989 / NM_001370785.2; = p.R358C on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs1303951422, COSV50498205, COSV50559882; called by muse, mutect2
- LRRC8B | c.1448C>T p.A483V | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.59); PolyPhen benign (0.017); catalogued as COSV58377075; called by muse, mutect2, varscan2
- LRRTM4 | c.1399C>T p.R467W | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV101297568, COSV69139331, COSV69140717; called by muse, varscan2
- LRTOMT | c.36G>T p.Q12H | Missense Mutation (SNP) | VAF 28/128 reads (22%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.808); catalogued as COSV56193662; called by muse, mutect2, varscan2
- LTBP2 | c.1756del p.V586* | Frame Shift Del (DEL) | VAF 11/75 reads (15%) | catalogued as rs776807257; called by mutect2, pindel, varscan2
- LZTR1 | c.842C>T p.P281L | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs1390048261, CD151200, COSV53147042, COSV53148013; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LZTR1 | c.1235G>A p.R412H | Missense Mutation (SNP) | VAF 37/122 reads (30%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.938); catalogued as rs935736801, COSV53151511; called by muse, mutect2, varscan2
- MAGEE2 | c.689_690del p.F230Cfs*15 | Frame Shift Del (DEL) | VAF 8/38 reads (21%) | catalogued as rs750349188; called by mutect2, pindel, varscan2
- MAP11 | c.1438G>A p.V480M | Missense Mutation (SNP) | VAF 36/141 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as rs754643547, COSV57588202; called by muse, mutect2, varscan2
- MAP1B | c.3478G>A p.V1160I | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs773567258, COSV57106040; called by muse, mutect2, varscan2
- MAP2K6 | c.248G>A p.R83Q | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.883); catalogued as rs1426115901, COSV63005503; called by muse, mutect2, varscan2
- MAP2K7 | c.1022C>T p.P341L | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67607667; called by muse, varscan2
- MAP3K14 | c.2405G>A p.S802N | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.519); catalogued as COSV60925029; called by muse, mutect2, varscan2
- MARCO | c.1349A>G p.E450G | Missense Mutation (SNP) | VAF 27/89 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as COSV59058421; called by muse, mutect2, varscan2
- MARS1 | c.2531C>T p.A844V | Missense Mutation (SNP) | VAF 43/217 reads (20%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs773914259, COSV56258603; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MAST1 | c.3299A>G p.K1100R | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.485); catalogued as COSV52254585; called by muse, mutect2, varscan2
- MATK | c.1400G>A p.R467H (on ENST00000310132 / NM_139355.3; = p.R468H on NM_002378.4) | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.89); catalogued as rs576533347, COSV59556621; called by muse, mutect2, varscan2
- MBP | c.109C>T p.R37W | Missense Mutation (SNP) | VAF 52/265 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.249); catalogued as rs1242231426, COSV63559394; called by muse, mutect2, varscan2
- MBTPS2 | c.1060C>T p.R354C | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.825); catalogued as COSV65268989; called by muse, mutect2
- MC5R | c.646G>A p.V216I | Missense Mutation (SNP) | VAF 88/404 reads (22%) | SIFT tolerated (0.27); PolyPhen benign (0.026); catalogued as rs150713702; called by muse, mutect2
- MCF2L | c.842C>T p.A281V (on ENST00000375608; = p.A249V on NM_024979.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs373112614; called by muse, mutect2, varscan2
- MCM10 | c.1034C>T p.T345M (on ENST00000484800 / NM_182751.3; = p.T344M on NM_018518.5) | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.997); catalogued as rs769266273, COSV66336725; called by muse, mutect2, varscan2
- MED23 | c.2258G>A p.R753H | Missense Mutation (SNP) | VAF 26/113 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV63437151; called by muse, mutect2, varscan2
- MEIOC | c.721C>T p.R241* | Nonsense Mutation (SNP) | VAF 27/122 reads (22%) | catalogued as COSV63441447; called by muse, mutect2, varscan2
- METTL3 | c.1523G>A p.R508H | Missense Mutation (SNP) | VAF 41/147 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52971230; called by muse, mutect2, varscan2
- MFAP5 | c.272G>A p.C91Y | Missense Mutation (SNP) | VAF 29/105 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); catalogued as rs1443899571, COSV63946295; called by muse, mutect2, varscan2
- MGA | c.7303C>T p.R2435W (on ENST00000219905 / NM_001164273.1; = p.R2226W on NM_001080541.2) | Missense Mutation (SNP) | VAF 28/88 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs779811318, COSV54947919; called by muse, mutect2, varscan2
- MGAM | c.5330C>T p.T1777M | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.029); catalogued as rs778740556, COSV72075785; called by muse, mutect2, varscan2
- MIDEAS | c.939del p.N314Tfs*4 | Frame Shift Del (DEL) | VAF 21/77 reads (27%) | catalogued as rs762448666; called by mutect2, pindel, varscan2
- MINK1 | c.1046C>T p.S349L | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as rs768445086, COSV61793248; called by muse, mutect2, varscan2
- MIXL1 | c.556G>A p.E186K | Missense Mutation (SNP) | VAF 54/199 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs769845658, COSV64729003; called by muse, mutect2, varscan2
- MLLT6 | c.370G>A p.E124K | Missense Mutation (SNP) | VAF 31/100 reads (31%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.92); catalogued as rs763752411; called by muse, mutect2, varscan2
- MLX | c.712A>G p.K238E | Missense Mutation (SNP) | VAF 49/241 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV53818881; called by muse, mutect2, varscan2
- MORC4 | c.2687G>A p.R896H | Missense Mutation (SNP) | VAF 9/90 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs772865513, COSV55243507, COSV55246432; called by muse, mutect2, varscan2
- MPEG1 | c.1018C>T p.R340C | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.822); catalogued as rs540845788, COSV57094901; called by muse, mutect2, varscan2
- MPP4 | c.179C>T p.P60L | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.644); catalogued as rs749297609, COSV59634306; called by muse, mutect2, varscan2
- MRGPRD | c.410G>A p.R137Q | Missense Mutation (SNP) | VAF 31/114 reads (27%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.577); catalogued as rs754681703, COSV58424128; called by muse, mutect2, varscan2
- MROH2B | c.2797G>A p.G933R | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68189272; called by muse, mutect2, varscan2
- MROH5 | c.2626C>T p.R876C | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.388); catalogued as rs934882600, COSV71302831; called by muse, mutect2, varscan2
- MRPL19 | c.481G>A p.E161K | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1188904829, COSV62567964; called by muse, mutect2, varscan2
- MSH3 | c.2971T>C p.Y991H | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.708); catalogued as COSV54163673; called by muse, mutect2, varscan2
- MTA2 | c.1442G>A p.R481Q | Missense Mutation (SNP) | VAF 47/198 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.037); catalogued as rs746902489, COSV53471945; called by muse, mutect2, varscan2
- MTHFSD | c.272T>C p.L91P (on ENST00000360900 / NM_001159377.2; = p.L90P on NM_022764.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/340 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100530480; called by muse, mutect2
- MTM1 | c.1730C>T p.A577V | Missense Mutation (SNP) | VAF 31/117 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.08); catalogued as rs1557415146, COSV60337620; called by muse, mutect2, varscan2
- MUC6 | c.2896G>A p.V966M | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.336); catalogued as rs868111683, COSV70149676; called by muse, mutect2, varscan2
- MUS81 | c.1087C>T p.R363C | Missense Mutation (SNP) | VAF 45/233 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.747); catalogued as rs766623994, COSV57261462; called by muse, mutect2, varscan2
- MYH14 | c.2867G>A p.R956H | Missense Mutation (SNP) | VAF 28/136 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as rs747892579, COSV51830605; called by muse, mutect2, varscan2
- MYH3 | c.749G>A p.R250Q | Missense Mutation (SNP) | VAF 29/96 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs775849117, COSV56865210; called by muse, mutect2, varscan2
- MYH7B | c.5389C>T p.R1797W | Missense Mutation (SNP) | VAF 61/220 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs1216216330, COSV52684344; called by muse, mutect2, varscan2
- MYNN | c.1133G>A p.R378H | Missense Mutation (SNP) | VAF 32/96 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1282480786, COSV62992315; called by muse, mutect2, varscan2
- MYO15A | c.4717G>A p.A1573T | Missense Mutation (SNP) | VAF 24/100 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.028); catalogued as rs760537217, COSV52765549; called by muse, varscan2
- MYO15A | c.5767C>T p.R1923C | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.019); catalogued as rs753471215, COSV52765554, COSV99232249; called by muse, mutect2, varscan2
- MYO1D | c.569G>A p.R190Q | Missense Mutation (SNP) | VAF 27/90 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs780113381, COSV100554589, COSV59022936; called by muse, mutect2, varscan2
- MYT1L | c.3089C>T p.P1030L | Missense Mutation (SNP) | VAF 42/149 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.104); catalogued as COSV67704798; called by muse, mutect2, varscan2
- NAALAD2 | c.1124C>A p.A375D | Missense Mutation (SNP) | VAF 45/144 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.221); catalogued as COSV58965917; called by muse, mutect2, varscan2
- NACC1 | c.643C>T p.R215W | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.617); catalogued as rs1269661062, COSV52835920; called by muse, mutect2, varscan2
- NADK2 | c.586G>A p.V196I (on ENST00000381937 / NM_001085411.3; = p.V33I on NM_153013.4) | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.989); catalogued as rs775180461, COSV56939492; called by muse, mutect2, varscan2
- NARF | c.466C>T p.R156C | Missense Mutation (SNP) | VAF 37/132 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0.048); catalogued as rs202006583, COSV59111092; called by muse, mutect2, varscan2
- NAT10 | c.308G>A p.R103H | Missense Mutation (SNP) | VAF 28/86 reads (33%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.649); catalogued as rs770413727, COSV57666166; called by muse, mutect2, varscan2
- NCAPH2 | c.503G>A p.R168H | Missense Mutation (SNP) | VAF 49/187 reads (26%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.88); catalogued as rs745560670, COSV55371860; called by muse, mutect2, varscan2
- NCOA6 | c.2762G>A p.R921Q | Missense Mutation (SNP) | VAF 30/209 reads (14%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.994); catalogued as rs773179995, COSV62867665; called by muse, mutect2, varscan2
- NCOA7 | c.2269C>T p.R757C | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1211512940, COSV57660242; called by muse, mutect2, varscan2
- NCSTN | c.1301G>A p.R434Q | Missense Mutation (SNP) | VAF 54/206 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.017); catalogued as rs200487987, COSV54191615; called by muse, mutect2, varscan2
- NCSTN | c.2074G>A p.A692T | Missense Mutation (SNP) | VAF 25/143 reads (17%) | SIFT tolerated (0.28); PolyPhen benign (0.034); catalogued as COSV54191622; called by muse, mutect2, varscan2
- NDC80 | c.1771A>G p.T591A | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.014); catalogued as COSV55249750; called by muse, mutect2, varscan2
- NDST1 | c.1409G>A p.R470H | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs754297456, COSV55790684; called by muse, mutect2, varscan2
- NDUFS1 | c.1126G>T p.G376* | Nonsense Mutation (SNP) | VAF 19/61 reads (31%) | catalogued as COSV51913685; called by muse, mutect2, varscan2
- NEDD1 | c.1796C>T p.T599M | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs762167068, COSV57146424; called by muse, mutect2, varscan2
- NEDD4 | c.784C>T p.R262C | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.132); catalogued as rs746091972, COSV59066472; called by muse, mutect2, varscan2
- NEFL | c.515G>A p.R172H | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.953); catalogued as COSV55336970; called by muse, mutect2
- NEK6 | c.811G>A p.G271R | Missense Mutation (SNP) | VAF 45/147 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0.156); catalogued as rs779084313, COSV57217972; called by muse, mutect2, varscan2
- NF2 | c.1397G>A p.R466Q | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.845); catalogued as rs866689896, COSV58519900, COSV58530561; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NFATC1 | c.2091C>T p.N697= | Splice Region (SNP) | VAF 14/209 reads (7%) | catalogued as rs772857723, COSV53707821, COSV99501831; called by muse, mutect2
- NFATC2 | c.754C>T p.R252W | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65360684; called by muse, mutect2, varscan2
- NID1 | c.2480A>G p.Q827R | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT tolerated (0.24); PolyPhen benign (0.077); catalogued as COSV51628755; called by muse, mutect2, varscan2
- NIPA2 | c.568G>A p.A190T | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.358); catalogued as rs373772836; called by muse, mutect2, varscan2
- NIPBL | c.7208G>A p.R2403H | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56965194; called by muse, mutect2, varscan2
- NKX2-5 | c.160G>T p.E54* | Nonsense Mutation (SNP) | VAF 7/25 reads (28%) | catalogued as CM1110284, COSV61300005; called by muse, varscan2
- NLGN3 | c.2332G>A p.G778S (on ENST00000358741 / NM_181303.2; = p.G758S on NM_018977.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/106 reads (27%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.018); catalogued as rs17857401, COSV100704625; called by muse, mutect2, varscan2
- NOC2L | c.451G>A p.V151I | Missense Mutation (SNP) | VAF 113/438 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs1391413076, COSV58533511; called by muse, mutect2, varscan2
- NOMO1 | c.2585C>T p.A862V | Missense Mutation (SNP) | VAF 36/185 reads (19%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.59); catalogued as rs200199653, COSV55060355; called by muse, mutect2, varscan2
- NOS3 | c.1087G>A p.G363S | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.655); catalogued as rs572058640, COSV52489743; called by muse, mutect2, varscan2
- NOTCH1 | c.5759T>C p.L1920P | Missense Mutation (SNP) | VAF 18/95 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.946); catalogued as COSV53092323; called by muse, mutect2, varscan2
- NOTCH3 | c.5744G>A p.R1915H | Missense Mutation (SNP) | VAF 48/170 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747223569, COSV54640179; called by muse, mutect2, varscan2
- NR0B2 | c.292C>T p.L98F | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV54260157, COSV99574894; called by mutect2, varscan2
- NRXN2 | c.1729C>T p.R577W | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs752810328, COSV55462742; called by muse, mutect2, varscan2
- NSD2 | c.778C>T p.R260C | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV56396194; called by muse, mutect2, varscan2
- NTSR1 | c.464C>T p.T155M | Missense Mutation (SNP) | VAF 21/97 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs368494260; called by muse, mutect2, varscan2
- NUMA1 | c.1616T>C p.L539P | Missense Mutation (SNP) | VAF 49/187 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV61183559, COSV61190860; called by muse, mutect2, varscan2
- NUP54 | c.1003C>T p.R335* | Nonsense Mutation (SNP) | VAF 15/66 reads (23%) | catalogued as rs763061508, COSV53577330, COSV99345169; called by muse, mutect2, varscan2
- NUP62 | c.1552C>T p.R518W | Missense Mutation (SNP) | VAF 26/112 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs369812142; called by muse, mutect2, varscan2
- NUP85 | c.1538G>A p.R513Q | Missense Mutation (SNP) | VAF 59/210 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0.019); catalogued as rs149330582, COSV55458942; called by muse, mutect2, varscan2
- NXNL2 | c.65C>A p.A22E | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV65474778; called by muse, mutect2, varscan2
- NYNRIN | c.4700G>A p.R1567H | Missense Mutation (SNP) | VAF 35/118 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs769142864, COSV66844901; called by muse, mutect2, varscan2
- OGFR | c.1172G>T p.R391L | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.011); catalogued as COSV51702600; called by muse, mutect2, varscan2
- OLFML2B | c.127G>A p.E43K | Missense Mutation (SNP) | VAF 44/169 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.129); catalogued as rs776955703, COSV54200295; called by muse, mutect2, varscan2
- OPRK1 | c.557C>T p.S186L | Missense Mutation (SNP) | VAF 20/104 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.71); catalogued as rs143457105; called by muse, mutect2, varscan2
- OR51T1 | c.224T>C p.L75P | Missense Mutation (SNP) | VAF 39/302 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59027962; called by muse, mutect2, varscan2
- OR7C1 | c.365G>A p.R122H | Missense Mutation (SNP) | VAF 44/176 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs756541110, COSV50183626; called by muse, mutect2, varscan2
- OR8D2 | c.485G>A p.R162H | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs776771740, COSV62488310; called by muse, mutect2, varscan2
- OSBPL3 | c.1595T>C p.L532P | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1380732149, COSV57662269; called by muse, mutect2, varscan2
- OTOF | c.2870A>G p.K957R (on ENST00000272371 / NM_194248.3; = p.K210R on NM_004802.4) | Missense Mutation (SNP) | VAF 26/121 reads (21%) | SIFT tolerated (0.35); PolyPhen benign (0.092); catalogued as rs763893792, COSV55518477; called by muse, mutect2, varscan2
- P4HB | c.286G>A p.V96M | Missense Mutation (SNP) | VAF 54/218 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1567842828, COSV58942896; called by muse, mutect2, varscan2
- PAGE1 | c.287C>T p.A96V | Missense Mutation (SNP) | VAF 26/139 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0.152); catalogued as COSV65998187; called by muse, mutect2, varscan2
- PAIP1 | c.1423C>T p.R475C | Missense Mutation (SNP) | VAF 56/216 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.451); catalogued as rs759381679, COSV59087750; called by muse, mutect2, varscan2
- PAK6 | c.1909C>T p.R637W | Missense Mutation (SNP) | VAF 41/140 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs766710648, COSV53047749; called by muse, mutect2, varscan2
- PALM2AKAP2 | c.208C>T p.R70W (on ENST00000374531 / NM_001037293.2; = p.R68W on NM_007203.5) | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs752297384, COSV57118999; called by muse, mutect2, varscan2
- PAN2 | c.2652C>T p.G884= (on ENST00000425394 / NM_001127460.3; = p.G880= on NM_014871.5) | Splice Region (SNP) | VAF 25/84 reads (30%) | catalogued as rs767055164, COSV57753204; called by muse, mutect2, varscan2
- PAOX | c.313G>A p.G105R | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.935); catalogued as rs1424217015, COSV99529977; called by muse, mutect2, varscan2
- PAQR4 | c.169C>T p.L57= | Splice Region (SNP) | VAF 27/136 reads (20%) | catalogued as rs771612587, COSV51892779; called by muse, mutect2, varscan2
- PAQR5 | c.86G>A p.R29H | Missense Mutation (SNP) | VAF 64/211 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1020138881, COSV61819139; called by muse, mutect2, varscan2
- PATZ1 | c.413C>T p.T138M | Missense Mutation (SNP) | VAF 13/228 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1191199632, COSV99315452; called by muse, mutect2
- PCCA | c.1169G>A p.R390H | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs1192444349, COSV66198474; called by muse, mutect2, varscan2
- PCDH18 | c.2669A>G p.D890G | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT tolerated (0.75); PolyPhen benign (0.001); catalogued as COSV61271945; called by muse, mutect2
- PCDHA4 | c.1931G>A p.R644H | Missense Mutation (SNP) | VAF 49/211 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.082); catalogued as COSV63540150; called by muse, mutect2, varscan2
- PCDHA7 | c.991G>A p.A331T | Missense Mutation (SNP) | VAF 24/508 reads (5%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.066); catalogued as rs1418607679, COSV100971658; called by muse, mutect2
- PCDHB12 | c.596C>T p.A199V | Missense Mutation (SNP) | VAF 108/394 reads (27%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.02); catalogued as COSV53396775; called by muse, mutect2, varscan2
- PCDHB4 | c.2131C>T p.R711W | Missense Mutation (SNP) | VAF 31/132 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.941); catalogued as COSV52023102; called by muse, varscan2
- PCDHB6 | c.1963A>G p.T655A | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); catalogued as rs1563893326, COSV99170507; called by muse, mutect2, varscan2
- PCDHB8 | c.454G>A p.A152T | Missense Mutation (SNP) | VAF 25/146 reads (17%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0); catalogued as rs782153442, COSV99177177; called by muse, mutect2
- PCDHGA11 | c.2156G>A p.R719H | Missense Mutation (SNP) | VAF 73/279 reads (26%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.028); catalogued as COSV53895933; called by muse, mutect2, varscan2
- PCDHGA3 | c.145G>A p.A49T | Missense Mutation (SNP) | VAF 14/108 reads (13%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.382); catalogued as COSV53894034; called by muse, varscan2
- PCDHGA3 | c.1108G>A p.D370N | Missense Mutation (SNP) | VAF 13/306 reads (4%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV99542544; called by muse, mutect2
- PCDHGA5 | c.800C>T p.T267M | Missense Mutation (SNP) | VAF 11/111 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.963); catalogued as rs766093939, COSV53927286; called by muse, mutect2
- PCSK9 | c.908G>A p.R303H | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as COSV100135399, COSV56163865; called by muse, mutect2
- PDCD11 | c.1912T>C p.L638= | Splice Region (SNP) | VAF 131/255 reads (51%) | catalogued as rs1168224601, COSV63935282; called by muse, mutect2, varscan2
- PDE3A | c.3421C>T p.Q1141* | Nonsense Mutation (SNP) | VAF 5/33 reads (15%) | catalogued as rs780952258, COSV62982374; called by muse, mutect2, varscan2
- PEX11A | c.248G>A p.R83H | Missense Mutation (SNP) | VAF 32/108 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs531108695, COSV55585108; called by muse, mutect2, varscan2
- PGAM4 | c.62G>A p.R21H | Missense Mutation (SNP) | VAF 24/104 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.046); catalogued as COSV58453567; called by muse, mutect2, varscan2
- PGAP6 | c.1874T>G p.M625R | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51742378; called by muse, mutect2, varscan2
- PHC1 | c.1666C>T p.R556W | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.93); catalogued as rs864309586, COSV101418672; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PHC3 | c.398C>A p.P133H (on ENST00000494943 / NM_001308116.2; = p.P145H on NM_024947.4) | Missense Mutation (SNP) | VAF 10/101 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63051681; called by muse, mutect2, varscan2
- PHF2 | c.1475del p.K492Rfs*6 | Frame Shift Del (DEL) | VAF 12/51 reads (24%) | catalogued as rs769717544; called by mutect2, varscan2
- PHLPP1 | c.1678C>T p.R560C | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1029370896, COSV53026246; called by muse, mutect2, varscan2
- PI4KB | c.1952G>A p.R651H (on ENST00000368873 / NM_001369623.1; = p.R663H on NM_002651.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.608); catalogued as rs1190417371, COSV55017128, COSV55020083; called by muse, mutect2, varscan2
- PIK3CD | c.58G>A p.V20I | Missense Mutation (SNP) | VAF 39/190 reads (21%) | SIFT tolerated (0.88); PolyPhen benign (0.01); catalogued as rs143116020; called by muse, mutect2, varscan2
- PIK3CD | c.454G>A p.A152T | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.56); PolyPhen benign (0.018); catalogued as rs138463758; called by muse, mutect2, varscan2
- PIK3CD | c.2353C>T p.R785W | Missense Mutation (SNP) | VAF 17/90 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63128827; called by muse, mutect2, varscan2
- PITPNM1 | c.3055G>A p.G1019S | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.127); catalogued as rs1465884161, COSV54161831; called by muse, mutect2, varscan2
- PKD1L2 | c.374C>A p.P125H | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.794); catalogued as COSV100450080; called by muse, mutect2
- PKHD1 | c.8834G>A p.R2945H | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs1208940193, COSV61889464; called by muse, mutect2, varscan2
- PKP1 | c.2085-2A>G p.X695_splice | Splice Site (SNP) | VAF 7/62 reads (11%) | catalogued as COSV55825201; called by muse, mutect2, varscan2
- PKP4 | c.1118A>C p.E373A | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.64); PolyPhen benign (0.404); catalogued as COSV67679352; called by muse, mutect2, varscan2
- PLCXD3 | c.221G>A p.R74Q | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.968); catalogued as rs751201584, COSV60614634; called by muse, mutect2, varscan2
- PLCZ1 | c.1573C>T p.R525C | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.027); catalogued as rs764883389, COSV56858403; called by muse, mutect2, varscan2
- PLD2 | c.1834C>T p.R612C | Missense Mutation (SNP) | VAF 29/127 reads (23%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.731); catalogued as rs778592024, COSV54009667; called by muse, mutect2, varscan2
- PLD4 | c.991G>A p.A331T | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs372484745; called by muse, mutect2, varscan2
- PLEKHG4 | c.2141A>G p.Q714R | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs1362459660, COSV58575060; called by muse, mutect2
- PLEKHG5 | c.904C>T p.R302W (on ENST00000400915 / NM_001042663.3; = p.R265W on NM_020631.6) | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs879253921, COSV61705799; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PLXNA3 | c.236C>T p.P79L | Missense Mutation (SNP) | VAF 6/99 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs782350039, COSV63755014; called by muse, mutect2
- PLXNA4 | c.4645G>A p.A1549T | Missense Mutation (SNP) | VAF 43/198 reads (22%) | SIFT tolerated (0.51); PolyPhen benign (0.023); catalogued as COSV58109175; called by muse, mutect2, varscan2
- PLXNB3 | c.4273A>G p.T1425A | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); catalogued as COSV62801956; called by muse, mutect2, varscan2
- PNPLA6 | c.3071C>T p.A1024V (on ENST00000414982 / NM_001166111.2; = p.A976V on NM_006702.5) | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs761558516, COSV55384600; called by muse, mutect2, varscan2
- POLE | c.305C>T p.P102L | Missense Mutation (SNP) | VAF 20/104 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770323795, COSV57690204; called by muse, mutect2, varscan2
- POLE | c.100C>T p.R34C | Missense Mutation (SNP) | VAF 36/141 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as rs771051323, COSV57682651; called by muse, mutect2, varscan2
- POLG | c.3382C>T p.R1128C | Missense Mutation (SNP) | VAF 31/90 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs755544706, COSV51525085; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- POTEF | c.296G>A p.G99D | Missense Mutation (SNP) | VAF 66/426 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.931); catalogued as COSV62544059; called by muse, mutect2, varscan2
- POU2F3 | c.260A>G p.D87G | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.453); catalogued as COSV52797540; called by muse, mutect2, varscan2
- PPAN-P2RY11 | c.2191C>T p.P731S | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.139); catalogued as COSV53455944; called by muse, mutect2, varscan2
- PPFIA2 | c.2548C>T p.R850* | Nonsense Mutation (SNP) | VAF 20/76 reads (26%) | catalogued as COSV61053265; called by muse, mutect2, varscan2
- PPP5C | c.1199G>A p.R400Q | Missense Mutation (SNP) | VAF 33/160 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1156419988, COSV50144046; called by muse, mutect2, varscan2
- PRAG1 | c.3992G>A p.G1331E | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58166616; called by muse, mutect2, varscan2
- PRAME | c.13C>T p.R5C | Missense Mutation (SNP) | VAF 39/181 reads (22%) | SIFT tolerated, low confidence (0.14); PolyPhen possibly damaging (0.556); catalogued as rs765572331, COSV67161646; called by muse, mutect2, varscan2
- PRPF8 | c.5622G>A p.V1874= | Splice Region (SNP) | VAF 11/202 reads (5%) | catalogued as rs1160648801, COSV100517703; called by muse, mutect2
- PRR12 | c.3053G>A p.R1018H (on ENST00000615927; = p.R1839H on NM_020719.3) | Missense Mutation (SNP) | VAF 32/160 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as rs373493220; called by muse, mutect2, varscan2
- PSMD3 | c.620C>T p.A207V | Missense Mutation (SNP) | VAF 41/179 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.019); catalogued as COSV52858707; called by muse, mutect2, varscan2
- PTCH2 | c.1928G>A p.R643Q | Missense Mutation (SNP) | VAF 50/183 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs1206654652, COSV64713447; called by muse, mutect2, varscan2
- PTK2B | c.254G>A p.R85Q | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs147218792; called by muse, mutect2, varscan2
- PTPDC1 | c.95G>A p.R32H (on ENST00000375360 / NM_177995.3; = p.R84H on NM_152422.4) | Missense Mutation (SNP) | VAF 22/126 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as rs143596868; called by muse, mutect2, varscan2
- PTPN14 | c.3133C>T p.R1045* | Nonsense Mutation (SNP) | VAF 31/125 reads (25%) | catalogued as COSV65283843; called by muse, mutect2, varscan2
- PTPN22 | c.797G>T p.R266L | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63085497, COSV63086509; called by muse, mutect2, varscan2
- PTPRJ | c.3374G>A p.R1125H | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as rs374260795, COSV101394690; called by muse, mutect2, varscan2
- PTPRN2 | c.1817A>G p.Q606R | Missense Mutation (SNP) | VAF 97/396 reads (24%) | SIFT tolerated (0.79); PolyPhen benign (0.005); catalogued as COSV67059562; called by muse, mutect2, varscan2
- PXK | c.824T>C p.V275A | Missense Mutation (SNP) | VAF 30/101 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs765730965, COSV57094428; called by muse, mutect2, varscan2
- PYGB | c.1093-2A>G p.X365_splice | Splice Site (SNP) | VAF 61/218 reads (28%) | catalogued as COSV53822622; called by muse, mutect2, varscan2
- PYGM | c.686C>T p.T229M | Missense Mutation (SNP) | VAF 64/236 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); catalogued as rs751890543, COSV51227222; called by muse, mutect2, varscan2
- RAB3A | c.425A>G p.E142G | Missense Mutation (SNP) | VAF 64/281 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.699); catalogued as COSV55853818; called by muse, mutect2, varscan2
- RAB3B | c.197G>A p.R66H | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.986); catalogued as rs764753734, COSV63228318; called by muse, mutect2, varscan2
- RAB3GAP1 | c.815G>A p.C272Y | Missense Mutation (SNP) | VAF 30/231 reads (13%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.915); catalogued as COSV51488439; called by muse, mutect2, varscan2
- RAB3GAP2 | c.805A>G p.S269G | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.318); catalogued as rs751914149, COSV99424880; called by muse, mutect2
- RAD51AP1 | c.208del p.R70Dfs*21 (on ENST00000228843 / NM_001130862.2; = p.R70Gfs*4 on NM_006479.5) | Frame Shift Del (DEL) | VAF 6/24 reads (25%) | catalogued as rs745353960; called by mutect2, pindel, varscan2
- RADIL | c.934G>A p.A312T | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT tolerated (0.45); PolyPhen benign (0.006); catalogued as rs746063859, COSV68199784; called by muse, mutect2
- RAET1E | c.568G>A p.D190N | Missense Mutation (SNP) | VAF 39/162 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs777647534, COSV61722358; called by muse, mutect2, varscan2
- RAG1 | c.2291G>A p.R764H | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs768809293, CM1313160, CM153012, COSV55026538, COSV55027660; called by muse, mutect2, varscan2
- RALGPS2 | c.1007A>G p.H336R | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.35); PolyPhen benign (0.075); catalogued as rs1042167507, COSV61339737; called by muse, mutect2, varscan2
- RAPGEF3 | c.773C>T p.A258V (on ENST00000389212; = p.A216V on NM_006105.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 81/361 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs765086897, COSV50237197; called by muse, mutect2, varscan2
- RAVER1 | c.503G>A p.R168H | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs200937169; called by muse, mutect2, varscan2
- RBFOX2 | c.485C>T p.T162I (on ENST00000438146 / NM_001349995.2; = p.T92I on NM_014309.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 44/194 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.099); catalogued as rs1468251197, COSV53268111; called by muse, mutect2, varscan2
- RBM10 | c.2113G>A p.E705K | Missense Mutation (SNP) | VAF 50/224 reads (22%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.846); catalogued as rs887995752, COSV61307871, COSV61309449; called by muse, mutect2, varscan2
- RBP3 | c.3394C>T p.R1132C | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1186084355; called by muse, mutect2, varscan2
- RC3H1 | c.26C>T p.T9M | Missense Mutation (SNP) | VAF 12/134 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs199537248, COSV51201542, COSV99281579; called by muse, mutect2
- RERE | c.1613A>T p.K538I | Missense Mutation (SNP) | VAF 32/164 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61950449; called by muse, mutect2, varscan2
- RGMA | c.671A>G p.Q224R | Missense Mutation (SNP) | VAF 25/129 reads (19%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.659); catalogued as COSV61236751; called by muse, mutect2, varscan2
- RHBDF2 | c.575G>A p.R192Q | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57421902; called by muse, mutect2, varscan2
- RHBG | c.23C>T p.A8V | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as rs753409271, COSV54809743; called by muse, mutect2, varscan2
- RHEX | c.142G>A p.A48T | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT tolerated (0.36); PolyPhen benign (0.007); catalogued as COSV100520055, COSV58979987; called by muse, mutect2, varscan2
- RHO | c.699C>T p.A233= | Splice Region (SNP) | VAF 41/190 reads (22%) | catalogued as rs1338813260, COSV56214579; called by muse, mutect2, varscan2
- RIC8B | c.761G>A p.R254H | Missense Mutation (SNP) | VAF 34/162 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs764723269, COSV62697029; called by muse, mutect2, varscan2
- RNF126 | c.301C>A p.Q101K | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.46); PolyPhen benign (0.114); catalogued as COSV52779465; called by muse, mutect2, varscan2
- RNF130 | c.695G>A p.R232H | Missense Mutation (SNP) | VAF 83/327 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.286); catalogued as rs751865376, COSV56148332; called by muse, mutect2, varscan2
- RNF207 | c.1189G>A p.V397I | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.06); catalogued as rs375305088; called by mutect2, varscan2
- RNF43 | c.1976del p.G659Vfs*41 | Frame Shift Del (DEL) | VAF 17/103 reads (17%) | catalogued as rs755128667, COSV68457540; called by mutect2, pindel, varscan2
- ROBO2 | c.3040G>A p.D1014N | Missense Mutation (SNP) | VAF 50/162 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.649); catalogued as rs751528165, COSV59905197; called by muse, mutect2, varscan2
- RP1L1 | c.608del p.K203Rfs*28 | Frame Shift Del (DEL) | VAF 16/97 reads (16%) | catalogued as COSV61445808; called by mutect2, pindel, varscan2
- RPAP1 | c.470C>T p.A157V | Missense Mutation (SNP) | VAF 36/139 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs575978774, COSV58538612; called by muse, mutect2, varscan2
- RPL21 | c.388C>T p.R130C | Missense Mutation (SNP) | VAF 12/118 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as COSV55389712; called by muse, mutect2
- RPUSD3 | c.889C>T p.R297C | Missense Mutation (SNP) | VAF 25/99 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.013); catalogued as rs377371328; called by muse, mutect2, varscan2
- RRBP1 | c.2704C>T p.R902W (on ENST00000377813 / NM_001365613.2; = p.R469W on NM_004587.3) | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as rs112056169, COSV55708319; called by muse, mutect2, varscan2
- RUNX1T1 | c.82T>C p.C28R | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as COSV56162182; called by muse, mutect2, varscan2
- RYR1 | c.7750C>T p.H2584Y | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as rs1330350845, COSV62089602; called by muse, mutect2, varscan2
- SAFB2 | c.2503C>T p.R835W | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as rs533605559, COSV53042259; called by muse, mutect2, varscan2
- SAFB2 | c.296G>A p.G99D | Missense Mutation (SNP) | VAF 12/321 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs1342462426, COSV53044484; called by muse, mutect2
- SALL2 | c.881G>A p.R294Q | Missense Mutation (SNP) | VAF 27/96 reads (28%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.994); catalogued as rs753189477, COSV58104956; called by muse, mutect2, varscan2
- SCLT1 | c.1269dup p.A424Sfs*12 | Frame Shift Ins (INS) | VAF 43/162 reads (27%) | catalogued as rs781735051; called by mutect2, varscan2
- SCN2A | c.4885C>T p.R1629C | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV51843815; called by muse, mutect2, varscan2
- SCRIB | c.338G>A p.S113N | Missense Mutation (SNP) | VAF 8/113 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100252219; called by muse, mutect2
- SCUBE1 | c.1093G>A p.E365K | Missense Mutation (SNP) | VAF 23/107 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.869); catalogued as rs1354921762, COSV100683002, COSV62616108; called by muse, mutect2, varscan2
- SDK1 | c.6252-2A>G p.X2084_splice | Splice Site (SNP) | VAF 14/53 reads (26%) | catalogued as COSV67387874; called by muse, mutect2, varscan2
- SEC24D | c.2714C>T p.A905V | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.628); catalogued as COSV54884682; called by muse, mutect2, varscan2
- SEMA3G | c.133C>T p.R45C | Missense Mutation (SNP) | VAF 67/208 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs756251735, COSV51598061; called by muse, mutect2, varscan2
- SERINC2 | c.487G>A p.G163S (on ENST00000373709 / NM_178865.5; = p.G167S on NM_018565.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 49/265 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs201000290, COSV65490723, COSV65491462; called by muse, mutect2
- SFI1 | c.232A>G p.T78A | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.049); catalogued as COSV66290080; called by muse, mutect2, varscan2
- SGF29 | c.304G>A p.G102S | Missense Mutation (SNP) | VAF 35/112 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.084); catalogued as rs774745658, COSV57683089; called by muse, mutect2, varscan2
- SH3BP4 | c.13C>T p.R5W | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.94); catalogued as rs149092399; called by muse, mutect2, varscan2
- SH3RF1 | c.173C>T p.S58L | Missense Mutation (SNP) | VAF 22/101 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.012); catalogued as rs765059674, COSV52925120; called by muse, mutect2, varscan2
- SH3TC1 | c.604C>A p.H202N | Missense Mutation (SNP) | VAF 36/153 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.433); catalogued as COSV55289541; called by muse, mutect2, varscan2
- SHBG | c.514C>A p.L172I | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.193); catalogued as COSV52647851; called by muse, mutect2, varscan2
- SHE | c.790G>A p.A264T | Missense Mutation (SNP) | VAF 34/109 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.014); catalogued as rs377651157; called by muse, mutect2, varscan2
- SHISA5 | c.323C>T p.A108V | Missense Mutation (SNP) | VAF 36/121 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.314); catalogued as rs770659092, COSV56497997; called by muse, mutect2, varscan2
- SIGLEC14 | c.358G>A p.V120M | Missense Mutation (SNP) | VAF 18/271 reads (7%) | SIFT tolerated (0.24); PolyPhen benign (0.149); catalogued as COSV55782864; called by muse, mutect2
- SIL1 | c.991C>T p.R331C | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs765721225, COSV54537361; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC10A4 | c.1190A>G p.D397G | Missense Mutation (SNP) | VAF 46/185 reads (25%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as COSV56719818; called by muse, mutect2, varscan2
- SLC24A3 | c.1325C>T p.S442L | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.045); catalogued as rs751279859, COSV60116231; called by muse, mutect2
- SLC27A2 | c.1025G>A p.R342Q | Missense Mutation (SNP) | VAF 33/137 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV51062527; called by muse, mutect2, varscan2
- SLC39A12 | c.743G>A p.R248H | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs755814869, COSV66201244, COSV66201612; called by muse, mutect2, varscan2
- SLC46A3 | c.185A>G p.Q62R | Missense Mutation (SNP) | VAF 38/140 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.039); catalogued as COSV57182778; called by muse, mutect2, varscan2
- SLC47A2 | c.695T>C p.V232A | Missense Mutation (SNP) | VAF 40/162 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV57630509; called by muse, mutect2, varscan2
- SLC4A11 | c.1153G>A p.A385T | Missense Mutation (SNP) | VAF 154/624 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs770563344, COSV66260714; called by muse, mutect2, varscan2
- SLC4A7 | c.442C>T p.R148* | Nonsense Mutation (SNP) | VAF 10/35 reads (29%) | catalogued as COSV55398191, COSV55402532; called by muse, mutect2, varscan2
- SLC66A1 | c.832C>T p.R278C | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.018); catalogued as rs1236152393, COSV64321392; called by muse, mutect2, varscan2
- SLC6A2 | c.1739C>T p.T580M | Missense Mutation (SNP) | VAF 31/128 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.017); catalogued as rs148686754, COSV54914858; called by muse, mutect2, varscan2
- SLC7A4 | c.296C>T p.T99M | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.953); catalogued as rs373190347; called by muse, mutect2, varscan2
- SLIT3 | c.703A>G p.T235A | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT tolerated (0.8); PolyPhen benign (0.006); catalogued as COSV60632238; called by muse, mutect2, varscan2
- SMAD7 | c.838C>T p.Q280* | Nonsense Mutation (SNP) | VAF 6/81 reads (7%) | catalogued as COSV100052976; called by muse, mutect2
- SMARCA2 | c.2530C>T p.R844W | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61806876; called by muse, mutect2
- SMC6 | c.1543C>T p.R515W | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.488); catalogued as rs760507314, COSV100705260; called by muse, mutect2, varscan2
- SMG1 | c.8078C>A p.P2693H | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV67174741; called by mutect2, varscan2
- SOCS6 | c.1399A>G p.N467D | Missense Mutation (SNP) | VAF 37/126 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV67547105; called by muse, mutect2, varscan2
- SOGA1 | c.3190T>C p.S1064P | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52930335; called by muse, mutect2, varscan2
- SORBS3 | c.1057C>T p.R353W | Missense Mutation (SNP) | VAF 33/124 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.549); catalogued as rs780345923, COSV53554846; called by muse, varscan2
- SOX9 | c.1420C>T p.R474C | Missense Mutation (SNP) | VAF 64/246 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55425121; called by muse, mutect2, varscan2
- SP4 | c.874A>G p.S292G | Missense Mutation (SNP) | VAF 66/229 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56026384; called by muse, mutect2, varscan2
- SPAG1 | c.394C>T p.R132C | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs769344647, COSV52558730, COSV52559172; called by muse, mutect2, varscan2
- SPG7 | c.1903G>A p.E635K (on ENST00000268704; = p.E642K on NM_003119.4) | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1202120338, COSV51954483; called by muse, mutect2, varscan2
- SPRED2 | c.898C>T p.R300W | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as rs1299658940, COSV62695787; called by muse, mutect2, varscan2
- SPTAN1 | c.1694G>A p.R565H | Missense Mutation (SNP) | VAF 28/114 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.389); catalogued as rs376897533; called by muse, mutect2, varscan2
- SPTB | c.2174G>T p.W725L | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); catalogued as COSV67634865; called by muse, mutect2, varscan2
- SPTBN1 | c.4795T>G p.F1599V | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.474); catalogued as COSV61693830; called by muse, mutect2, varscan2
- SRCIN1 | c.3587C>T p.S1196L (on ENST00000621492; = p.S1162L on NM_025248.3) | Missense Mutation (SNP) | VAF 30/108 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.73); catalogued as rs552819894; called by muse, mutect2, varscan2
- SREBF1 | c.677C>T p.T226M | Missense Mutation (SNP) | VAF 35/149 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.023); catalogued as rs70937019, CM061218; called by muse, mutect2, varscan2
- SRPX2 | c.787C>T p.R263C | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65934512; called by muse, mutect2
- ST3GAL2 | c.16C>T p.R6W | Missense Mutation (SNP) | VAF 17/62 reads (27%) | PolyPhen probably damaging (0.998); catalogued as rs759434739, COSV61595915; called by muse, mutect2, varscan2
- STK10 | c.1897G>A p.V633M | Missense Mutation (SNP) | VAF 35/179 reads (20%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.599); catalogued as rs765203214, COSV51578709; called by muse, mutect2, varscan2
- SUPT7L | c.868G>A p.E290K | Missense Mutation (SNP) | VAF 21/104 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.355); catalogued as rs970575929, COSV53117498; called by muse, mutect2, varscan2
- SYCP2 | c.3641G>C p.S1214T | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT tolerated (0.76); PolyPhen benign (0.007); catalogued as COSV62772369; called by muse, mutect2, varscan2
- SYT16 | c.1205G>A p.G402D | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); catalogued as rs777461212, COSV70859134; called by muse, mutect2, varscan2
- TAF2 | c.3377C>T p.A1126V | Missense Mutation (SNP) | VAF 31/126 reads (25%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs368237103, COSV65421001; called by muse, mutect2, varscan2
- TAMM41 | c.868C>T p.R290* | Nonsense Mutation (SNP) | VAF 26/121 reads (21%) | catalogued as rs753115954, COSV56071889; called by muse, mutect2, varscan2
- TAMM41 | c.433G>A p.E145K | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.775); catalogued as rs758721564, COSV56073243; called by muse, mutect2, varscan2
- TAOK2 | c.1430G>A p.R477H | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1278518808, COSV54240710; called by muse, mutect2, varscan2
- TATDN2 | c.227G>A p.R76H | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.007); catalogued as rs193243038, COSV55052967; called by muse, mutect2, varscan2
- TBX3 | c.2026G>A p.A676T (on ENST00000257566 / NM_016569.4; = p.A656T on NM_005996.4) | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs1013102657, COSV57472702, COSV57473679; called by muse, mutect2, varscan2
- TCF20 | c.1847G>A p.R616Q | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); catalogued as rs372882393, COSV59494412; called by muse, mutect2, varscan2
- TCF7 | c.1046C>T p.S349L | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.777); catalogued as rs373163251; called by muse, mutect2, varscan2
- TCHH | c.1921_1923del p.E641del | In Frame Del (DEL) | VAF 18/160 reads (11%) | catalogued as rs755471114; called by pindel, varscan2
- TCTN3 | c.667G>A p.V223I | Missense Mutation (SNP) | VAF 25/42 reads (60%) | SIFT tolerated (0.15); PolyPhen benign (0.022); catalogued as COSV56451279; called by muse, mutect2, varscan2
- TEAD2 | c.1300G>A p.E434K | Missense Mutation (SNP) | VAF 55/186 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as rs556204126, COSV60545238; called by muse, mutect2, varscan2
- TEAD4 | c.67A>G p.T23A | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT tolerated (0.82); PolyPhen benign (0.001); catalogued as COSV63282440; called by muse, mutect2, varscan2
- TECTA | c.2032G>A p.E678K | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.484); catalogued as rs727504744, COSV50800199; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TENM3 | c.4271A>G p.K1424R | Missense Mutation (SNP) | VAF 29/84 reads (35%) | SIFT tolerated (0.62); PolyPhen benign (0.003); catalogued as COSV69318684; called by muse, mutect2, varscan2
- TENT4A | c.2240G>A p.G747D | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.281); catalogued as COSV50100516; called by muse, mutect2, varscan2
- TENT4A | c.2335C>A p.H779N | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.101); catalogued as rs748296365, COSV50094534; called by muse, mutect2, varscan2
- TEX55 | c.1096C>T p.R366C | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs775313662, COSV55211285; called by muse, mutect2, varscan2
- TFDP1 | c.502C>T p.R168C | Missense Mutation (SNP) | VAF 68/228 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64742371; called by muse, mutect2, varscan2
- TFDP3 | c.760G>A p.V254M | Missense Mutation (SNP) | VAF 102/305 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.233); catalogued as rs865906208, COSV59537121; called by muse, mutect2, varscan2
- TG | c.2231C>T p.A744V | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as COSV55069578; called by muse, mutect2, varscan2
- THADA | c.3994G>A p.A1332T | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as rs374567143, COSV57691482; called by muse, mutect2, varscan2
- THAP8 | c.514G>A p.G172R | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT tolerated (0.66); PolyPhen benign (0.404); catalogued as rs776227508, COSV53077976, COSV99495818; called by muse, mutect2
- THBS2 | c.235C>T p.R79W | Missense Mutation (SNP) | VAF 69/243 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.708); catalogued as rs149505756; called by muse, mutect2, varscan2
- THEG | c.1064G>A p.R355H | Missense Mutation (SNP) | VAF 150/486 reads (31%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs1211993267, COSV61073691; called by muse, mutect2, varscan2
- THSD4 | c.568C>T p.R190W | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as rs773635180, COSV55979890; called by muse, mutect2, varscan2
- TIAM2 | c.3894G>T p.E1298D | Missense Mutation (SNP) | VAF 49/203 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51644462; called by muse, mutect2, varscan2
- TIGD5 | c.1711G>A p.G571R | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.57); PolyPhen benign (0.027); catalogued as rs760644970, COSV55309571; called by muse, mutect2, varscan2
- TJP2 | c.632G>A p.R211H | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.43); PolyPhen benign (0.08); catalogued as COSV55263594; called by muse, mutect2
- TK2 | c.317C>T p.S106L (on ENST00000299697; = p.S162L on NM_004614.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 58/263 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as rs774806103, COSV55283988; called by muse, mutect2, varscan2
- TLR5 | c.590C>T p.T197M | Missense Mutation (SNP) | VAF 37/140 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0.04); catalogued as rs146146738; called by muse, mutect2, varscan2
- TMC8 | c.674T>C p.V225A | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV59211435; called by muse, mutect2, varscan2
- TMED7-TICAM2 | c.832G>A p.G278R | Missense Mutation (SNP) | VAF 33/143 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.972); catalogued as COSV56696245; called by muse, mutect2, varscan2
- TMEM121 | c.608G>A p.S203N | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT tolerated (0.17); PolyPhen benign (0.219); catalogued as COSV66796684; called by muse, mutect2, varscan2
- TMEM132B | c.119C>T p.T40M | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.035); catalogued as rs373468338; called by muse, mutect2
- TMEM132D | c.1688G>A p.R563Q | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.423); catalogued as rs1022917530, COSV67159866; called by muse, mutect2
- TMEM156 | c.185A>G p.Q62R | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.022); catalogued as COSV60745645; called by muse, mutect2, varscan2
- TMEM163 | c.424G>A p.A142T | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV56112781; called by muse, mutect2, varscan2
- TMEM98 | c.425T>C p.V142A | Missense Mutation (SNP) | VAF 37/169 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.868); catalogued as COSV55583602; called by muse, mutect2, varscan2
- TNKS1BP1 | c.611C>T p.T204M | Missense Mutation (SNP) | VAF 41/134 reads (31%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs368145617; called by muse, mutect2, varscan2
- TNRC18 | c.1562C>T p.T521M | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as rs1317710865, COSV101259491; called by muse, mutect2
- TOGARAM1 | c.219G>A p.M73I | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as COSV61889330; called by muse, varscan2
- TOGARAM1 | c.292C>T p.R98W | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV61887886, COSV61889333; called by muse, varscan2
- TOPBP1 | c.3022C>T p.R1008W | Missense Mutation (SNP) | VAF 25/86 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.012); catalogued as rs369186269; called by muse, mutect2, varscan2
- TPR | c.1654C>T p.R552C | Missense Mutation (SNP) | VAF 35/127 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.048); catalogued as rs373572751; called by muse, mutect2, varscan2
- TRAPPC10 | c.2959G>A p.D987N | Missense Mutation (SNP) | VAF 96/292 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV52378723; called by muse, mutect2, varscan2
- TRBJ2-2 | c.10G>A p.G4R | Missense Mutation (SNP) | VAF 39/137 reads (28%) | catalogued as rs782749919; called by muse, mutect2, varscan2
- TRIM10 | c.209G>A p.R70Q | Missense Mutation (SNP) | VAF 44/216 reads (20%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.992); catalogued as rs750915862, COSV64989753; called by muse, mutect2
- TRIM17 | c.250G>A p.A84T | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.1); catalogued as COSV54384216; called by muse, mutect2, varscan2
- TRIM46 | c.2044G>A p.G682S | Missense Mutation (SNP) | VAF 93/264 reads (35%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs139008733; called by muse, mutect2, varscan2
- TRIM6 | c.1291C>T p.R431C | Missense Mutation (SNP) | VAF 41/224 reads (18%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.998); catalogued as rs1382721000, COSV53478952; called by muse, varscan2
- TRNT1 | c.251C>T p.A84V | Missense Mutation (SNP) | VAF 20/126 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); catalogued as COSV52408898, COSV52409553; called by muse, mutect2, varscan2
- TRPM8 | c.117C>T p.S39= | Splice Region (SNP) | VAF 17/76 reads (22%) | catalogued as rs377496653; called by muse, mutect2, varscan2
- TRPV3 | c.2251G>A p.E751K | Missense Mutation (SNP) | VAF 18/118 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs777339146, COSV56795749; called by muse, mutect2, varscan2
- TSC22D4 | c.1045C>T p.R349W | Missense Mutation (SNP) | VAF 21/93 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs143784300; called by muse, mutect2, varscan2
- TTC21A | c.2072C>T p.S691F | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.118); catalogued as COSV57189367; called by muse, mutect2, varscan2
- TTC38 | c.971G>A p.S324N | Missense Mutation (SNP) | VAF 28/122 reads (23%) | SIFT tolerated (0.3); PolyPhen benign (0.071); catalogued as COSV66843525; called by muse, mutect2, varscan2
- TTI1 | c.2800C>T p.R934C | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs575066309, COSV65063391; called by muse, mutect2, varscan2
- TTLL13P | c.590G>A p.R197H | Missense Mutation (SNP) | VAF 40/113 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV60039988; called by muse, mutect2, varscan2
- TTN | c.61771G>A p.V20591M (on ENST00000591111; = p.V13167M on NM_003319.4) | Missense Mutation (SNP) | VAF 13/59 reads (22%) | PolyPhen possibly damaging (0.847); catalogued as COSV60332126; called by muse, mutect2, varscan2
- TTN | c.54596G>A p.S18199N (on ENST00000591111; = p.S10775N on NM_003319.4) | Missense Mutation (SNP) | VAF 21/90 reads (23%) | PolyPhen possibly damaging (0.797); catalogued as COSV60332181; called by muse, mutect2, varscan2
- TTN | c.28570A>G p.M9524V (on ENST00000591111; = p.M8597V on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/107 reads (22%) | PolyPhen benign (0.124); catalogued as COSV60332216; called by muse, mutect2, varscan2
- TTYH2 | c.1399C>T p.Q467* | Nonsense Mutation (SNP) | VAF 25/93 reads (27%) | catalogued as COSV53913287; called by muse, mutect2, varscan2
- TUBA4A | c.661C>T p.R221C | Missense Mutation (SNP) | VAF 143/629 reads (23%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.086); catalogued as rs1312490496, COSV50280095; called by muse, mutect2, varscan2
- TUBB8 | c.1291G>A p.E431K | Missense Mutation (SNP) | VAF 8/182 reads (4%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.001); catalogued as rs540119672; called by muse, mutect2
- TUT1 | c.2212C>T p.R738W | Missense Mutation (SNP) | VAF 28/118 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.109); catalogued as COSV53468671, COSV53471934; called by muse, mutect2, varscan2
- TUT1 | c.1927C>T p.R643W | Missense Mutation (SNP) | VAF 42/262 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs761919342, COSV53471938; called by muse, mutect2, varscan2
- TUT1 | c.364C>T p.R122C | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765973002, COSV53468504; called by muse, mutect2
- UBE2A | c.449G>A p.R150H | Missense Mutation (SNP) | VAF 27/136 reads (20%) | SIFT tolerated (0.4); PolyPhen benign (0.026); catalogued as COSV60636783, COSV60637132; called by muse, mutect2, varscan2
- UBE2O | c.1549C>A p.P517T | Missense Mutation (SNP) | VAF 129/471 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV60067571; called by muse, mutect2, varscan2
- UBXN7 | c.1351C>T p.R451C | Missense Mutation (SNP) | VAF 24/123 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs748648908, COSV56357635; called by muse, mutect2, varscan2
- UHRF1BP1L | c.2285G>A p.R762Q | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.266); catalogued as rs765722745, COSV54434243, COSV54436099; called by muse, mutect2, varscan2
454 further variants in this file (89 protein-altering or splice-affecting, 340 silent, 25 other) are not listed here.
